Somatic mutation profile of tumor specimen C3L-09189-01 (aliquot CPT0532390006) from CPTAC case C3L-09189, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 72.2 years (26,377 days).
Specimen C3L-09189-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Fundus Of Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80af0cae-9393-4902-b654-eb2d0f0b791e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09189-31 (Blood Derived Normal), aliquot CPT0532540002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a699a0bb-0acf-4940-ba5e-c88428339eb8

The open-access MAF lists 757 somatic variants for this specimen: 538 protein-altering or splice-affecting, 197 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 367, Silent 197, Frame Shift Del 109, Frame Shift Ins 26, Nonsense Mutation 23, Intron 11, In Frame Del 10, 3'UTR 4, 5'Flank 3, Splice Region 2, 5'UTR 2, RNA 2.

Variants (750 of 757; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN1 | c.6388G>A p.E2130K | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs794728334, CM067392, COSV57317339; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GRIN2B | c.2539C>T p.R847* | Nonsense Mutation (SNP) | VAF 88/244 reads (36%) | catalogued as rs879253931, COSV74206073; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 50/236 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SACS | c.8793del p.K2931Nfs*22 | Frame Shift Del (DEL) | VAF 62/217 reads (29%) | catalogued as rs767871841, CD056854; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- SMARCA4 | c.3608G>A p.R1203H | Missense Mutation (SNP) | VAF 109/330 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs770680174, CM1310765, COSV60803832; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AAMP | c.44del p.P15Hfs*5 | Frame Shift Del (DEL) | VAF 89/332 reads (27%) | catalogued as rs751284215; called by mutect2, pindel, varscan2
- AARS2 | c.706del p.Q236Sfs*3 | Frame Shift Del (DEL) | VAF 192/432 reads (44%) | catalogued as rs1253616133; called by mutect2, pindel, varscan2
- ABCA13 | c.13570G>A p.A4524T | Missense Mutation (SNP) | VAF 61/241 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs1163099421, COSV68948669; called by muse, mutect2, varscan2
- ABCA2 | c.2014G>A p.A672T (on ENST00000614293; = p.A642T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 134/367 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.8); catalogued as rs1259215973, COSV55800634; called by muse, mutect2, varscan2
- ABCA3 | c.3812G>A p.R1271Q | Missense Mutation (SNP) | VAF 83/256 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs371099401; called by muse, mutect2, varscan2
- ABL2 | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 131/463 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV62666870; called by muse, mutect2, varscan2
- AC134980.2 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 140/532 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.078); catalogued as COSV60907932; called by muse, mutect2, varscan2
- ACKR2 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 98/197 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs866153853; called by muse, mutect2, varscan2
- ADAM11 | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 64/249 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs369212131; called by muse, mutect2
- ADCY8 | c.2111A>G p.Y704C | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53899360; called by muse, mutect2, varscan2
- ADGRE5 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 55/357 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs370160434; called by muse, mutect2, varscan2
- ADGRL2 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 98/300 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1003335830, COSV54655876; called by muse, varscan2
- AIFM1 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 118/187 reads (63%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs780914409; called by muse, mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 78/257 reads (30%) | catalogued as COSV62339755; called by mutect2, varscan2
- AMOT | c.2975C>T p.A992V (on ENST00000371959 / NM_001113490.1; = p.A583V on NM_133265.3) | Missense Mutation (SNP) | VAF 149/250 reads (60%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs1453459963; called by muse, mutect2, varscan2
- ANKRD20A1 | c.1376del p.N459Ifs*5 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs1296524808; called by mutect2, varscan2
- ANKRD31 | c.1533del p.G512Vfs*20 | Frame Shift Del (DEL) | VAF 58/237 reads (24%) | catalogued as rs1279723268; called by mutect2, pindel, varscan2
- ANLN | c.3118C>T p.R1040C | Missense Mutation (SNP) | VAF 70/246 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.772); catalogued as rs371189817; called by muse, mutect2, varscan2
- AP1M1 | c.163del p.V55Sfs*182 | Frame Shift Del (DEL) | VAF 99/358 reads (28%) | catalogued as rs753324780, COSV52227333; called by mutect2, pindel, varscan2
- ARHGAP17 | c.2440del p.Q814Nfs*23 (on ENST00000289968 / NM_001006634.3; = p.Q736Nfs*23 on NM_018054.6) | Frame Shift Del (DEL) | VAF 137/413 reads (33%) | catalogued as rs773922861; called by mutect2, varscan2
- ARHGEF1 | c.1088del p.P363Qfs*53 | Frame Shift Del (DEL) | VAF 110/367 reads (30%) | catalogued as COSV61526641; called by mutect2, pindel, varscan2
- ARHGEF10L | c.1150G>A p.V384M | Missense Mutation (SNP) | VAF 103/343 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as rs773305597; called by muse, mutect2, varscan2
- ARID1A | c.1189G>A p.G397R | Missense Mutation (SNP) | VAF 113/305 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as rs199828681; called by muse, mutect2, varscan2
- ARID5B | c.1489del p.I497* | Frame Shift Del (DEL) | VAF 75/289 reads (26%) | catalogued as rs201178069; called by mutect2, pindel, varscan2
- ASPSCR1 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 110/398 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.066); catalogued as rs368728773; called by muse, varscan2
- ATP13A5 | c.2357G>A p.R786H | Missense Mutation (SNP) | VAF 76/211 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs368258320, COSV100665175; called by muse, mutect2, varscan2
- ATP2B2 | c.1069G>A p.G357S (on ENST00000352432; = p.G323S on NM_001683.5) | Missense Mutation (SNP) | VAF 90/337 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.818); catalogued as rs1444840288, COSV59491773; called by muse, mutect2, varscan2
- ATP2B4 | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 95/302 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as rs370097553, COSV58175563; called by muse, mutect2, varscan2
- AURKB | c.578G>T p.G193V | Missense Mutation (SNP) | VAF 70/240 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV60245042; called by muse, mutect2, varscan2
- AVPI1 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 155/461 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as rs770933514, COSV65697422; called by muse, mutect2, varscan2
- BECN2 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 155/394 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV61560426; called by muse, mutect2, varscan2
- BTNL2 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 106/451 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs1169506634; called by muse, mutect2, varscan2
- C16orf54 | c.424G>A p.V142I | Missense Mutation (SNP) | VAF 143/465 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs754320429; called by muse, mutect2, varscan2
- CACHD1 | c.910G>A p.V304M | Missense Mutation (SNP) | VAF 89/259 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs767389262, COSV51559112; called by muse, mutect2, varscan2
- CACNA1H | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 115/343 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as rs778637721, COSV61999184; called by muse, mutect2, varscan2
- CACNG7 | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 33/245 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs764997446, COSV99712133; called by muse, mutect2, varscan2
- CALCRL | c.923del p.F308Sfs*3 | Frame Shift Del (DEL) | VAF 38/145 reads (26%) | catalogued as rs1422497140; called by mutect2, pindel, varscan2
- CASKIN1 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 92/294 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779323369, COSV58873606; called by muse, mutect2, varscan2
- CATSPER4 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 68/273 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs199601379; called by muse, mutect2, varscan2
- CCDC168 | c.17011A>C p.S5671R | Missense Mutation (SNP) | VAF 105/262 reads (40%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.629); catalogued as rs1235053039; called by muse, mutect2, varscan2
- CCNJ | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 76/283 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.832); catalogued as rs201944303; called by muse, mutect2, varscan2
- CD1D | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 99/287 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as rs757831900, COSV100939662; called by muse, mutect2, varscan2
- CDH24 | c.2135del p.P712Rfs*129 | Frame Shift Del (DEL) | VAF 98/316 reads (31%) | catalogued as rs752398646; called by mutect2, varscan2
- CDIP1 | c.290dup p.G98Rfs*37 | Frame Shift Ins (INS) | VAF 118/452 reads (26%) | catalogued as rs1246931296; called by pindel, varscan2
- CELSR2 | c.6458G>A p.R2153Q | Missense Mutation (SNP) | VAF 112/343 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.301); catalogued as rs771675760; called by muse, mutect2, varscan2
- CENPA | c.172A>G p.T58A | Missense Mutation (SNP) | VAF 74/223 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as COSV51982739; called by muse, mutect2, varscan2
- CFAP44 | c.3416G>A p.R1139Q | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1345977528, COSV67248485; called by muse, mutect2, varscan2
- CFAP46 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 83/246 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs369847869; called by muse, mutect2, varscan2
- CFAP91 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 90/255 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs747341452, COSV56340952; called by muse, mutect2, varscan2
- CGN | c.2981G>A p.R994H | Missense Mutation (SNP) | VAF 52/225 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371586724; called by muse, mutect2, varscan2
- CHPF2 | c.1318C>T p.R440W | Missense Mutation (SNP) | VAF 131/423 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs929593395, COSV50388907; called by muse, mutect2, varscan2
- CHRNA5 | c.639dup p.D214* | Frame Shift Ins (INS) | VAF 80/210 reads (38%) | catalogued as rs1202847637; called by mutect2, varscan2
- CNBD2 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 78/219 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV100839109; called by muse, mutect2, varscan2
- COASY | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762858854; called by muse, mutect2, varscan2
- COL6A3 | c.3424G>A p.D1142N | Missense Mutation (SNP) | VAF 107/365 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.183); catalogued as rs777599612, COSV55090588; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CREBBP | c.6596A>T p.Q2199L | Missense Mutation (SNP) | VAF 104/328 reads (32%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.039); catalogued as rs765821935, COSV52114705; called by muse, varscan2
- CYP27A1 | c.207_209del p.F70del | In Frame Del (DEL) | VAF 99/336 reads (29%) | catalogued as rs774193477; called by pindel, varscan2
- DBN1 | c.1762_1764del p.K588del | In Frame Del (DEL) | VAF 120/387 reads (31%) | catalogued as rs766663179; called by mutect2, pindel, varscan2
- DBX2 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 184/506 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1020862088; called by muse, mutect2, varscan2
- DCAF1 | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV60042387; called by muse, mutect2, varscan2
- DCAF12L2 | c.644G>A p.G215D | Missense Mutation (SNP) | VAF 161/262 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63582112; called by muse, mutect2, varscan2
- DDO | c.877C>T p.R293* (on ENST00000368924 / NM_001368172.1; = p.R234* on NM_004032.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 124/465 reads (27%) | catalogued as rs142527860; called by muse, mutect2, varscan2
- DGKD | c.189G>T p.Q63H (on ENST00000264057 / NM_152879.3; = p.Q19H on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/296 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV51103663; called by muse, mutect2, varscan2
- DGKI | c.2239C>T p.R747* | Nonsense Mutation (SNP) | VAF 44/159 reads (28%) | catalogued as rs748651549, COSV99935627, COSV99936293; called by muse, mutect2, varscan2
- DHX38 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 79/278 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.885); catalogued as rs778702496, COSV51700585; called by muse, mutect2, varscan2
- DIDO1 | c.6410G>A p.R2137Q | Missense Mutation (SNP) | VAF 157/456 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV56635172; called by muse, mutect2, varscan2
- DIO3 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 148/386 reads (38%) | SIFT tolerated (0.48); PolyPhen probably damaging (1); catalogued as rs371556514; called by muse, mutect2, varscan2
- DKK4 | c.33G>A p.W11* | Nonsense Mutation (SNP) | VAF 82/282 reads (29%) | catalogued as rs769424916; called by muse, mutect2, varscan2
- DNAH9 | c.377C>A p.P126H | Missense Mutation (SNP) | VAF 97/377 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.682); catalogued as COSV99306453; called by muse, mutect2, varscan2
- DNMT3B | c.2060del p.G687Vfs*14 | Frame Shift Del (DEL) | VAF 85/331 reads (26%) | catalogued as rs1258311276, COSV52417886; called by mutect2, pindel, varscan2
- DOCK6 | c.4840G>A p.A1614T | Missense Mutation (SNP) | VAF 134/449 reads (30%) | SIFT tolerated (0.82); PolyPhen benign (0.195); catalogued as rs1163568915; called by muse, mutect2, varscan2
- DOP1B | c.6377C>T p.T2126M | Missense Mutation (SNP) | VAF 73/207 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs369366196; called by muse, mutect2, varscan2
- DSCAML1 | c.388G>A p.V130M (on ENST00000321322; = p.V70M on NM_020693.4) | Missense Mutation (SNP) | VAF 148/412 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1393957887, COSV58382031; called by muse, mutect2, varscan2
- DTWD1 | c.395A>G p.E132G | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1442108862, COSV99233736; called by muse, varscan2
- DTX1 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1353630847; called by muse, mutect2, varscan2
- DZIP1L | c.1712del p.P571Hfs*14 | Frame Shift Del (DEL) | VAF 112/415 reads (27%) | catalogued as rs1220979198, COSV100551426; called by mutect2, pindel, varscan2
- ELOVL2 | c.557A>G p.Y186C | Missense Mutation (SNP) | VAF 125/286 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs79554116; called by muse, mutect2, varscan2
- EMP2 | c.299T>C p.I100T | Missense Mutation (SNP) | VAF 68/190 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as COSV63996083; called by muse, mutect2, varscan2
- EPHA10 | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 95/392 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs529538143; called by muse, mutect2, varscan2
- EPHB1 | c.1985G>T p.R662L | Missense Mutation (SNP) | VAF 90/275 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756316035, COSV67656481, COSV67666280; called by muse, mutect2, varscan2
- ERBB3 | c.1433C>T p.T478M | Missense Mutation (SNP) | VAF 75/268 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as rs1010091317; called by muse, mutect2, varscan2
- ERICH4 | c.64dup p.Q22Pfs*29 | Frame Shift Ins (INS) | VAF 92/310 reads (30%) | catalogued as rs567420399; called by mutect2, varscan2
- EXOSC9 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 63/230 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs202225797, COSV99697173; called by muse, mutect2, varscan2
- F5 | c.585del p.T197Pfs*2 | Frame Shift Del (DEL) | VAF 45/179 reads (25%) | catalogued as CD034471; called by mutect2, pindel, varscan2
- FAM160A1 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 106/338 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as rs868550454, COSV70707234; called by muse, mutect2, varscan2
- FAM20B | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as rs749646614, COSV55381780; called by muse, mutect2, varscan2
- FAM53A | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 137/406 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as rs770438437, COSV57401857; called by muse, mutect2, varscan2
- FAM53B | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 94/294 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV55101302; called by muse, mutect2, varscan2
- FAT3 | c.11825G>A p.R3942Q | Missense Mutation (SNP) | VAF 70/248 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.296); catalogued as rs752185173, COSV53110508; called by muse, mutect2, varscan2
- FBXO24 | c.904C>T p.R302C (on ENST00000241071 / NM_033506.3; = p.R340C on NM_012172.5) | Missense Mutation (SNP) | VAF 104/318 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as rs776780277, COSV53825258; called by muse, mutect2, varscan2
- FES | c.1966C>T p.R656W | Missense Mutation (SNP) | VAF 149/492 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1030254748, COSV60998220; called by muse, mutect2, varscan2
- FHAD1 | c.3397G>A p.D1133N | Missense Mutation (SNP) | VAF 59/209 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs181011016; called by muse, mutect2, varscan2
- FHIT | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 81/166 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1271249118, COSV59314200; called by muse, mutect2, varscan2
- FOXF2 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 214/800 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.419); catalogued as rs759285624, COSV52527118, COSV99453362; called by muse, mutect2, varscan2
- FRMD1 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 140/559 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); catalogued as rs142513431; called by muse, mutect2, varscan2
- FSD2 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV58009437; called by muse, mutect2, varscan2
- FSIP2 | c.1139del p.N380Tfs*16 | Frame Shift Del (DEL) | VAF 44/175 reads (25%) | catalogued as rs1559014390; called by mutect2, varscan2
- FSTL4 | c.2095C>T p.R699C | Missense Mutation (SNP) | VAF 134/361 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs374862530, COSV54789894; called by muse, mutect2, varscan2
- GOLGA8H | c.830T>C p.V277A | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as rs766928092; called by muse, mutect2, varscan2
- GPC2 | c.1047del p.D350Tfs*24 | Frame Shift Del (DEL) | VAF 107/361 reads (30%) | catalogued as rs748011069, COSV52786506; called by mutect2, pindel, varscan2
- GPC5 | c.379dup p.C127Lfs*21 | Frame Shift Ins (INS) | VAF 58/223 reads (26%) | catalogued as rs775279047; called by mutect2, pindel, varscan2
- GPR142 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 118/348 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs150650994; called by muse, varscan2
- GPR25 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 119/357 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.154); catalogued as rs774335788, COSV100421743; called by muse, mutect2, varscan2
- GPR32 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 115/359 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs190167592, COSV54514534; called by muse, mutect2, varscan2
- GRIK5 | c.1744C>T p.R582C | Missense Mutation (SNP) | VAF 116/347 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs763923047, COSV53480930; called by muse, mutect2, varscan2
- GRSF1 | c.679A>G p.I227V | Missense Mutation (SNP) | VAF 52/195 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0.024); catalogued as rs765301394; called by muse, mutect2, varscan2
- GSDMD | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 123/373 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.077); catalogued as rs147352021; called by muse, mutect2, varscan2
- GUCY1A1 | c.530A>G p.Q177R | Missense Mutation (SNP) | VAF 94/305 reads (31%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs894845578; called by muse, mutect2, varscan2
- HBE1 | c.302C>A p.P101H | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53079881, COSV99496326; called by muse, mutect2, varscan2
- HDGF | c.149del p.F50Sfs*105 | Frame Shift Del (DEL) | VAF 62/196 reads (32%) | catalogued as COSV100625709; called by mutect2, varscan2
- HECTD4 | c.12769G>A p.V4257M | Missense Mutation (SNP) | VAF 123/374 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1389293618; called by muse, mutect2, varscan2
- HELZ | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 70/216 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs763814134, COSV62381040; called by muse, mutect2, varscan2
- HLA-DOA | c.416T>C p.F139S | Missense Mutation (SNP) | VAF 346/808 reads (43%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.984); catalogued as rs977572383; called by muse, mutect2
- HOXD9 | c.244G>A p.V82M | Missense Mutation (SNP) | VAF 153/488 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.203); catalogued as COSV50893411; called by muse, mutect2, varscan2
- HPCAL1 | c.373G>A p.V125M | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs373345229; called by muse, mutect2, varscan2
- ICA1L | c.111del p.E38Rfs*30 | Frame Shift Del (DEL) | VAF 64/246 reads (26%) | catalogued as rs1330717036; called by mutect2, pindel, varscan2
- ICAM4 | c.437G>A p.G146D | Missense Mutation (SNP) | VAF 40/348 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs750773201; called by muse, mutect2, varscan2
- IGFN1 | c.3437C>T p.P1146L (on ENST00000295591 / NM_001367841.1; = p.P3603L on NM_001164586.2) | Missense Mutation (SNP) | VAF 97/284 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as rs769280747, COSV55166492; called by muse, varscan2
- IGHV1-2 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 84/268 reads (31%) | catalogued as rs368557039; called by muse, varscan2
- INTS11 | c.1063G>A p.V355M | Missense Mutation (SNP) | VAF 81/261 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs756719002; called by muse, mutect2, varscan2
- ITGA6 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 71/239 reads (30%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.749); catalogued as rs750401792; called by muse, mutect2, varscan2
- JPH2 | c.1823C>T p.T608M | Missense Mutation (SNP) | VAF 134/437 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs750776027, COSV65904793; called by muse, mutect2, varscan2
- JPH3 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 170/496 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs199923310, COSV52466294; called by muse, mutect2, varscan2
- KCNH2 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 50/189 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs747313232, COSV100059934; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNH4 | c.1389C>T p.G463= | Splice Region (SNP) | VAF 42/142 reads (30%) | catalogued as rs141904652; called by muse, mutect2, varscan2
- KCNJ4 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 140/375 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs753595753, COSV57856295; called by muse, mutect2, varscan2
- KDF1 | c.429del p.S144Afs*104 | Frame Shift Del (DEL) | VAF 44/502 reads (9%) | catalogued as COSV57671558; called by mutect2, pindel
- KDM2B | c.2706del p.K903Rfs*31 | Frame Shift Del (DEL) | VAF 146/494 reads (30%) | catalogued as COSV65645921; called by mutect2, pindel, varscan2
- KLHDC8B | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 119/242 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1419742528; called by muse, mutect2, varscan2
- KPNA7 | c.184dup p.T62Nfs*13 | Frame Shift Ins (INS) | VAF 78/254 reads (31%) | catalogued as rs746637129; called by mutect2, pindel, varscan2
- KRTAP4-7 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 210/605 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs1210310178, COSV66951250, COSV66952261; called by muse, mutect2, varscan2
- LARP4 | c.1118del p.N373Ifs*3 | Frame Shift Del (DEL) | VAF 53/180 reads (29%) | catalogued as rs1179425728; called by mutect2, pindel, varscan2
- LATS2 | c.1369G>A p.A457T | Missense Mutation (SNP) | VAF 142/405 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs1213156692; called by muse, varscan2
- LOXHD1 | c.3698C>T p.T1233M | Missense Mutation (SNP) | VAF 70/261 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as rs375951379, COSV104394760; called by muse, mutect2, varscan2
- LOXL2 | c.64del p.L22* | Frame Shift Del (DEL) | VAF 120/328 reads (37%) | catalogued as COSV66692377; called by mutect2, varscan2
- MAGI1 | c.2786G>A p.R929H (on ENST00000402939 / NM_001033057.2; = p.R957H on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 130/269 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.355); catalogued as rs368569997; called by muse, mutect2, varscan2
- MAGI2 | c.3251G>A p.R1084Q | Missense Mutation (SNP) | VAF 109/370 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.357); catalogued as rs775903666, COSV62686220; called by muse, mutect2, varscan2
- MAP4K4 | c.2209C>T p.L737F (on ENST00000347699 / NM_001242559.2; = p.L652F on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/163 reads (36%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.413); catalogued as rs1174682556; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 69/240 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767997804, COSV51721294; called by muse, varscan2
- MCOLN2 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 90/268 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs145109809; called by muse, mutect2, varscan2
- MEX3D | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 130/439 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66312344, COSV66312449; called by muse, mutect2, varscan2
- MFSD11 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 77/236 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs749609248, COSV100334051, COSV60622332; called by muse, mutect2, varscan2
- MGAT1 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 112/375 reads (30%) | PolyPhen probably damaging (0.974); catalogued as rs1448028839, COSV100286643; called by muse, mutect2, varscan2
- MPIG6B | c.320dup p.C108Lfs*72 | Frame Shift Ins (INS) | VAF 318/790 reads (40%) | catalogued as rs1343823890; called by mutect2, pindel, varscan2
- MTMR2 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.033); catalogued as rs779277108, COSV60578367; called by muse, mutect2, varscan2
- MUC16 | c.4648C>T p.H1550Y | Missense Mutation (SNP) | VAF 95/312 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.607); catalogued as rs1568926188; called by muse, mutect2, varscan2
- MYH11 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 133/379 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs1085307699, COSV55558416; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO15A | c.2083G>A p.G695S | Missense Mutation (SNP) | VAF 117/342 reads (34%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); catalogued as rs1184590256; called by muse, mutect2, varscan2
- MYO1A | c.3049G>A p.V1017I | Missense Mutation (SNP) | VAF 78/258 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs373699223; called by muse, varscan2
- MYO3A | c.29T>A p.I10N | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs375710366, COSV99778732; called by muse, mutect2, varscan2
- MYOC | c.1169T>A p.V390D | Missense Mutation (SNP) | VAF 91/351 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV50673832; called by muse, mutect2, varscan2
- NACA | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 65/193 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV63267767; called by muse, mutect2, varscan2
- NAV1 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 105/290 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs746653920; called by muse, mutect2, varscan2
- NAV3 | c.6254C>T p.A2085V (on ENST00000397909 / NM_001024383.2; = p.A2063V on NM_014903.6) | Missense Mutation (SNP) | VAF 76/226 reads (34%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.885); catalogued as COSV99886899; called by muse, mutect2, varscan2
- NDN | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 107/293 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs549529148, COSV100086387; called by muse, mutect2, varscan2
- NDUFA12 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 66/225 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.643); catalogued as rs148011078; called by muse, mutect2, varscan2
- NEB | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.997); catalogued as rs116678485, COSV51446818; called by muse, mutect2, varscan2
- NEFH | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 137/503 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs148074196; called by muse, mutect2, varscan2
- NELL1 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 11/263 reads (4%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.558); catalogued as rs908099186, COSV54262173; called by muse, mutect2
- NEURL1 | c.1583C>T p.A528V | Missense Mutation (SNP) | VAF 118/321 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs372474838; called by muse, mutect2, varscan2
- NEUROD6 | c.250A>G p.T84A | Missense Mutation (SNP) | VAF 119/359 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs370167291; called by muse, mutect2, varscan2
- NGF | c.187G>A p.V63M | Missense Mutation (SNP) | VAF 116/344 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.469); catalogued as rs750829893, COSV65688827; called by muse, mutect2, varscan2
- NKAP | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 87/134 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57630392; called by muse, mutect2, varscan2
- NOTUM | c.1439C>T p.P480L | Missense Mutation (SNP) | VAF 116/355 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1180128443; called by muse, mutect2, varscan2
- NRP2 | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 84/264 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs113330212, COSV55926636; called by muse, mutect2, varscan2
- NUDT13 | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 92/283 reads (33%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.973); catalogued as rs367709273; called by muse, mutect2, varscan2
- NUDT16L1 | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 115/327 reads (35%) | catalogued as rs770053173; called by muse, mutect2, varscan2
- OOSP1 | c.215A>G p.Y72C | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1194750522; called by muse, mutect2, varscan2
- OR2T8 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.086); catalogued as rs746072977; called by muse, mutect2, varscan2
- OR2Y1 | c.829del p.Y277Ifs*3 | Frame Shift Del (DEL) | VAF 63/254 reads (25%) | catalogued as COSV57137289; called by pindel, varscan2
- OR52B6 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 97/264 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as rs777058751; called by muse, mutect2, varscan2
- P4HB | c.1160del p.N387Tfs*118 | Frame Shift Del (DEL) | VAF 143/201 reads (71%) | catalogued as rs763394045; called by mutect2, varscan2
- PATL2 | c.743C>T p.T248M | Missense Mutation (SNP) | VAF 75/239 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs750451009; called by muse, mutect2, varscan2
- PBXIP1 | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 142/438 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs770126124, COSV100870145, COSV63776935; called by muse, mutect2, varscan2
- PCDH10 | c.1778C>T p.S593L | Missense Mutation (SNP) | VAF 164/505 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.18); catalogued as rs771704218, COSV52094615; called by muse, mutect2, varscan2
- PCDH10 | c.2984G>T p.G995V | Missense Mutation (SNP) | VAF 112/309 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV52100857; called by muse, mutect2, varscan2
- PCDHA4 | c.1543G>A p.G515S | Missense Mutation (SNP) | VAF 177/575 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554124735, COSV63540276; called by muse, mutect2, varscan2
- PCDHA4 | c.1901C>T p.T634M | Missense Mutation (SNP) | VAF 115/386 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.633); catalogued as rs1202399974, COSV63538657; called by muse, mutect2, varscan2
- PCDHB13 | c.918del p.K306Nfs*30 | Frame Shift Del (DEL) | VAF 61/209 reads (29%) | catalogued as rs782213177; called by mutect2, pindel, varscan2
- PCED1B | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 107/336 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71394915; called by muse, mutect2, varscan2
- PDIA5 | c.1157dup p.P387Afs*44 | Frame Shift Ins (INS) | VAF 34/160 reads (21%) | catalogued as rs766425459; called by mutect2, varscan2
- PDZD8 | c.3375_3377del p.E1125del | In Frame Del (DEL) | VAF 46/187 reads (25%) | catalogued as rs1368101924; called by pindel, varscan2
- PHF21A | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 128/365 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); catalogued as COSV99138303; called by muse, mutect2, varscan2
- PHKB | c.1929del p.G644Efs*2 | Frame Shift Del (DEL) | VAF 64/233 reads (27%) | catalogued as rs35494330; called by mutect2, pindel, varscan2
- PHLPP1 | c.3604C>T p.R1202C | Missense Mutation (SNP) | VAF 93/319 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs760057011, COSV53027309; called by muse, mutect2, varscan2
- PIPOX | c.1099A>G p.K367E | Missense Mutation (SNP) | VAF 97/315 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV60141356; called by muse, mutect2, varscan2
- PITPNC1 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 61/207 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55445494; called by muse, mutect2, varscan2
- PKD1 | c.755del p.P252Rfs*38 | Frame Shift Del (DEL) | VAF 153/468 reads (33%) | catalogued as CD1413102; called by mutect2, pindel, varscan2
- PLCL1 | c.670C>T p.R224* | Nonsense Mutation (SNP) | VAF 60/196 reads (31%) | catalogued as COSV70833848; called by muse, mutect2, varscan2
- PLEC | c.3014C>G p.A1005G (on ENST00000322810 / NM_201380.4; = p.A895G on NM_000445.5) | Missense Mutation (SNP) | VAF 109/306 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.056); catalogued as COSV100518142; called by muse, varscan2
- PLK4 | c.1183A>G p.T395A | Missense Mutation (SNP) | VAF 97/317 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs750062734; called by muse, mutect2, varscan2
- POLR3E | c.1049G>A p.C350Y | Missense Mutation (SNP) | VAF 64/305 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767132871, COSV55399434, COSV55400010; called by muse, mutect2, varscan2
- POM121C | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 59/264 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs1554474134; called by muse, mutect2, varscan2
- PPCDC | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 76/250 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs145355117, COSV100738781; called by muse, mutect2, varscan2
- PREX2 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 69/248 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.029); catalogued as rs745582647; called by muse, mutect2, varscan2
- PRKD1 | c.664C>T p.L222F | Missense Mutation (SNP) | VAF 90/264 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs984053198; called by muse, mutect2, varscan2
- PRKD2 | c.69del p.G24Afs*3 | Frame Shift Del (DEL) | VAF 146/499 reads (29%) | catalogued as COSV52189875; called by mutect2, pindel, varscan2
- PRMT7 | c.1074_1075del p.R358Sfs*9 | Frame Shift Del (DEL) | VAF 59/231 reads (26%) | catalogued as rs763953657; called by pindel, varscan2
- PRPF40A | c.877A>G p.T293A | Missense Mutation (SNP) | VAF 9/201 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as rs1020361759; called by muse, mutect2
- PRPF6 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 62/185 reads (34%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.787); catalogued as rs377270235; called by muse, mutect2, varscan2
- PTPRS | c.2846G>A p.R949H | Missense Mutation (SNP) | VAF 138/408 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs1370939047; called by muse, varscan2
- PWWP2B | c.257del p.P86Lfs*100 | Frame Shift Del (DEL) | VAF 79/280 reads (28%) | catalogued as rs1234606471; called by mutect2, pindel, varscan2
- RAD21 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1051321465, COSV52061152; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- RAI1 | c.2669C>T p.P890L | Missense Mutation (SNP) | VAF 169/479 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs745320469, COSV99884745; ClinVar: likely benign; called by muse, mutect2, varscan2
- RAPGEF1 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 152/398 reads (38%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.014); catalogued as rs1208058639, COSV100940885; called by muse, varscan2
- RASGRF1 | c.2195G>A p.R732H | Missense Mutation (SNP) | VAF 116/324 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.171); catalogued as rs753792264; called by muse, varscan2
- RCC2 | c.931C>T p.R311* | Nonsense Mutation (SNP) | VAF 106/350 reads (30%) | catalogued as rs1557623780, COSV64905748; called by muse, mutect2, varscan2
- RCSD1 | c.14C>A p.P5Q | Missense Mutation (SNP) | VAF 61/208 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as rs375805662; called by muse, mutect2, varscan2
- RET | c.3091G>A p.D1031N | Missense Mutation (SNP) | VAF 107/289 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs200989078, COSV60706028; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RFT1 | c.1408G>A p.V470I | Missense Mutation (SNP) | VAF 82/177 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs777508218; called by muse, mutect2, varscan2
- RHBDF1 | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 188/577 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs780810982; called by muse, mutect2, varscan2
- RIPOR2 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 141/264 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772795601; called by muse, mutect2, varscan2
- RLF | c.4255del p.Y1419Ifs*6 | Frame Shift Del (DEL) | VAF 81/275 reads (29%) | catalogued as COSV65652466; called by mutect2, pindel, varscan2
- RNF10 | c.1834C>T p.R612C | Missense Mutation (SNP) | VAF 79/255 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs754519126, COSV58044703; called by muse, mutect2, varscan2
- RNF10 | c.2391_2392del p.K798Tfs*96 | Frame Shift Del (DEL) | VAF 58/193 reads (30%) | catalogued as rs1436782263; called by mutect2, pindel, varscan2
- RNF39 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 202/816 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs776173276; called by muse, mutect2, varscan2
- ROBO2 | c.1705C>T p.Q569* | Nonsense Mutation (SNP) | VAF 47/97 reads (48%) | catalogued as COSV100170232, COSV59902892; called by muse, mutect2, varscan2
- RPS6KA1 | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 93/308 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs748150049; called by muse, mutect2, varscan2
- RUNX1T1 | c.273del p.S92Hfs*35 (on ENST00000265814 / NM_001198628.1; = p.S65Hfs*35 on NM_004349.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 72/297 reads (24%) | catalogued as rs1258994032; called by mutect2, pindel, varscan2
- RUSC2 | c.2318G>A p.R773Q | Missense Mutation (SNP) | VAF 125/381 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs991637509; called by muse, mutect2, varscan2
- SAFB | c.1876C>T p.R626C | Missense Mutation (SNP) | VAF 65/233 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs140739982; called by muse, mutect2, varscan2
- SCG2 | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 85/237 reads (36%) | catalogued as COSV59538877; called by muse, mutect2, varscan2
- SCML4 | c.403G>A p.V135I | Missense Mutation (SNP) | VAF 247/515 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1226255536, COSV64637228; called by muse, mutect2, varscan2
- SCN1A | c.4229del p.N1410Mfs*2 (on ENST00000303395 / NM_001202435.3; = p.N1399Mfs*2 on NM_006920.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 73/244 reads (30%) | catalogued as CD126553, COSV100319575; called by mutect2, pindel, varscan2
- SCO2 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 120/368 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as rs149750715; called by muse, mutect2, varscan2
- SCRIB | c.2408C>G p.A803G | Missense Mutation (SNP) | VAF 160/491 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57584248; called by muse, mutect2, varscan2
- SENP1 | c.1921C>T p.R641* | Nonsense Mutation (SNP) | VAF 70/254 reads (28%) | catalogued as COSV50299211; called by muse, mutect2, varscan2
- SERPINB13 | c.641T>C p.M214T | Missense Mutation (SNP) | VAF 65/202 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54030252; called by muse, mutect2, varscan2
- SFPQ | c.1771C>T p.R591C | Missense Mutation (SNP) | VAF 58/245 reads (24%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs779173588; called by muse, mutect2, varscan2
- SHISA2 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 24/446 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs775528667, COSV60110148; called by muse, mutect2
- SLC22A1 | c.1198G>A p.V400M | Missense Mutation (SNP) | VAF 237/470 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.244); catalogued as rs143522800; called by muse, mutect2, varscan2
- SLC26A7 | c.58dup p.Q20Pfs*3 | Frame Shift Ins (INS) | VAF 86/303 reads (28%) | catalogued as rs749030792; called by mutect2, pindel, varscan2
- SLC38A8 | c.1069G>A p.V357M | Missense Mutation (SNP) | VAF 145/464 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as rs368692039; called by muse, mutect2, varscan2
- SLC4A3 | c.1717C>T p.R573C | Missense Mutation (SNP) | VAF 72/238 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99812825; called by muse, mutect2, varscan2
- SLC5A11 | c.1093G>A p.V365M | Missense Mutation (SNP) | VAF 74/225 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs372298696; called by muse, mutect2, varscan2
- SLC6A7 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 93/332 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.899); catalogued as rs762989334, COSV100046499, COSV57940420, COSV57940921; called by muse, mutect2, varscan2
- SLITRK2 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 101/164 reads (62%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.893); catalogued as COSV100158069, COSV59424087; called by muse, mutect2, varscan2
- SLPI | c.306del p.N103Ifs*13 | Frame Shift Del (DEL) | VAF 103/309 reads (33%) | catalogued as rs745834619; called by mutect2, varscan2
- SMCO4 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 69/231 reads (30%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.009); catalogued as rs1354575103; called by muse, mutect2, varscan2
- SMIM28 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 182/401 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.209); catalogued as rs894336236; called by muse, mutect2, varscan2
- SMTNL2 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 21/652 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1185755831; called by muse, mutect2
- SOX1 | c.1061del p.G354Afs*29 | Frame Shift Del (DEL) | VAF 129/490 reads (26%) | catalogued as rs1173049043; called by mutect2, pindel, varscan2
- SOX7 | c.769del p.L257Wfs*14 | Frame Shift Del (DEL) | VAF 174/605 reads (29%) | catalogued as rs1478777952; called by mutect2, pindel, varscan2
- SPATA17 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 85/274 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs145142638; called by muse, mutect2, varscan2
- SPATA33 | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 146/454 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); catalogued as rs751840485; called by muse, mutect2, varscan2
- SPINK7 | c.87del p.V30Wfs*42 | Frame Shift Del (DEL) | VAF 36/139 reads (26%) | catalogued as rs747884448; called by mutect2, pindel, varscan2
- SPNS3 | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 155/500 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs200782432, COSV100337118; called by muse, mutect2, varscan2
- SPTB | c.6001C>T p.R2001C | Missense Mutation (SNP) | VAF 21/315 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376489437; called by muse, mutect2
- SRPK1 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 136/315 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.17); catalogued as rs1277363881, COSV60410831; called by muse, mutect2, varscan2
- STC1 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 56/198 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.27); catalogued as rs778531998, COSV51688654; called by muse, mutect2, varscan2
- STIM2 | c.1867C>T p.R623* | Nonsense Mutation (SNP) | VAF 63/224 reads (28%) | catalogued as rs1308963533; called by muse, mutect2, varscan2
- STK24 | c.992dup p.S332Qfs*2 | Frame Shift Ins (INS) | VAF 55/215 reads (26%) | catalogued as rs758627015; called by mutect2, pindel, varscan2
- SUGCT | c.1205C>T p.P402L (on ENST00000335693 / NM_001193313.2; = p.P428L on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/341 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750514599, COSV59354221; called by muse, mutect2, varscan2
- SYN2 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 79/230 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs767189621; called by muse, mutect2, varscan2
- TCN2 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 74/316 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757905563, COSV53192888; ClinVar: uncertain significance; called by muse, varscan2
- TENM4 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 138/409 reads (34%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.039); catalogued as rs757424213, COSV99573178; called by muse, mutect2, varscan2
- TET2 | c.3467A>G p.N1156S | Missense Mutation (SNP) | VAF 57/228 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.179); catalogued as COSV54438130; called by muse, mutect2, varscan2
- TFEC | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 51/159 reads (32%) | catalogued as rs747913528, COSV55397684, COSV99624319; called by muse, mutect2, varscan2
- TGIF2 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 100/278 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1212835258, COSV65836339; called by muse, mutect2, varscan2
- TMC6 | c.2169_2171del p.F724del | In Frame Del (DEL) | VAF 74/256 reads (29%) | catalogued as rs1391641839; called by pindel, varscan2
- TMEM132A | c.2875C>G p.R959G (on ENST00000453848 / NM_178031.3; = p.R960G on NM_017870.4) | Missense Mutation (SNP) | VAF 129/436 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99070846; called by mutect2, varscan2
- TMEM200C | c.726del p.A244Pfs*18 | Frame Shift Del (DEL) | VAF 45/296 reads (15%) | catalogued as rs775591992; called by mutect2, pindel, varscan2
- TMEM94 | c.657del p.F220Sfs*31 | Frame Shift Del (DEL) | VAF 94/405 reads (23%) | catalogued as rs753764149; called by mutect2, pindel, varscan2
- TNC | c.2116G>A p.A706T | Missense Mutation (SNP) | VAF 48/187 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201625385; called by muse, mutect2, varscan2
- TNFRSF1A | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 106/355 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV50614238; called by muse, mutect2, varscan2
- TP53TG3D | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated, low confidence (0.5); PolyPhen possibly damaging (0.695); catalogued as rs1308599216; called by mutect2, varscan2
- TPCN2 | c.2141C>T p.P714L | Missense Mutation (SNP) | VAF 114/349 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1565097318; called by muse, mutect2, varscan2
- TPST1 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 76/305 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV100507332; called by muse, mutect2, varscan2
- TRIB3 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 129/380 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as rs143437909; called by muse, mutect2, varscan2
- TRIM3 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 94/257 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs138201440; called by muse, mutect2, varscan2
- TRPM5 | c.983C>T p.T328M | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763058714, COSV50148622; called by muse, mutect2, varscan2
- TSG101 | c.467C>T p.T156M | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs746926397; called by muse, mutect2, varscan2
- TSHZ3 | c.2818G>A p.G940R | Missense Mutation (SNP) | VAF 28/400 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as rs769460173, COSV53664252; called by muse, mutect2
- TTC14 | c.903dup p.Q302Tfs*15 | Frame Shift Ins (INS) | VAF 52/155 reads (34%) | catalogued as rs1560072646; called by mutect2, varscan2
- TTN | c.50018_50020del p.E16673del (on ENST00000591111; = p.E9249del on NM_003319.4) | In Frame Del (DEL) | VAF 74/240 reads (31%) | catalogued as rs1553675991; called by pindel, varscan2
- TXNDC8 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 70/195 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370777037; called by muse, mutect2, varscan2
- UMODL1 | c.158C>T p.T53M | Missense Mutation (SNP) | VAF 98/323 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs766102738; called by muse, mutect2, varscan2
- UNC5A | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 82/307 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56172217; called by muse, mutect2, varscan2
- UNC79 | c.5026G>A p.V1676I (on ENST00000393151 / NM_001346218.2; = p.V1499I on NM_020818.5) | Missense Mutation (SNP) | VAF 138/446 reads (31%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.034); catalogued as rs1185628231, COSV56375602; called by muse, mutect2, varscan2
- UTS2R | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 162/538 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs913669442, COSV57454041; called by muse, mutect2, varscan2
- WNT9B | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 139/452 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as rs765555952, COSV99255014; called by muse, mutect2, varscan2
- YKT6 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 74/227 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs780133803, COSV56272711; called by muse, mutect2, varscan2
- ZAP70 | c.1066G>A p.V356M | Missense Mutation (SNP) | VAF 78/270 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1242353145; called by muse, mutect2, varscan2
- ZBTB1 | c.1147del p.S383Vfs*6 | Frame Shift Del (DEL) | VAF 54/182 reads (30%) | catalogued as rs747075448, COSV62437585; called by mutect2, varscan2
- ZCCHC4 | c.960del p.F320Lfs*19 | Frame Shift Del (DEL) | VAF 75/258 reads (29%) | catalogued as rs760215323; called by mutect2, pindel, varscan2
- ZDHHC24 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 124/390 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1265726554, COSV100130636; called by muse, mutect2, varscan2
- ZFPM1 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 152/517 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs768527783, COSV100128364; called by muse, mutect2, varscan2
- ZNF333 | c.1553G>A p.S518N | Missense Mutation (SNP) | VAF 83/277 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as rs367575525; called by muse, mutect2, varscan2
- ZNF43 | c.516dup p.L173Tfs*21 | Frame Shift Ins (INS) | VAF 47/162 reads (29%) | catalogued as rs748612562; called by mutect2, varscan2
- ZNF48 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 106/370 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs567018085, COSV100198001; called by muse, mutect2, varscan2
- ZNF507 | c.2219C>G p.T740R | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.019); catalogued as rs1250944117; called by muse, mutect2
- ZNF597 | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 85/324 reads (26%) | catalogued as rs755317229, COSV57085747; called by muse, mutect2, varscan2
- ZNF598 | c.2188G>A p.A730T | Missense Mutation (SNP) | VAF 84/308 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1207085630; called by muse, varscan2
- ZNF687 | c.2815del p.R939Vfs*10 | Frame Shift Del (DEL) | VAF 134/444 reads (30%) | catalogued as rs749403447; called by mutect2, pindel, varscan2
- ZNF735 | c.381dup p.C128Mfs*3 | Frame Shift Ins (INS) | VAF 48/156 reads (31%) | catalogued as rs781384768; called by mutect2, varscan2
- ZNF746 | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 81/241 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs144007946; called by muse, mutect2, varscan2
- ZNF835 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 44/422 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV73379624; called by muse, mutect2, varscan2
- ZNF862 | c.1787G>A p.R596H | Missense Mutation (SNP) | VAF 121/345 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs370138647; called by muse, mutect2, varscan2
- AAR2 | c.667G>C p.A223P | Missense Mutation (SNP) | VAF 106/323 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- ABI2 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 92/332 reads (28%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ABO | c.801del p.F268Sfs*20 | Frame Shift Del (DEL) | VAF 86/316 reads (27%) | called by mutect2, varscan2
- AC105001.2 | c.370G>T p.V124F | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- ADGRA2 | c.2429A>C p.N810T | Missense Mutation (SNP) | VAF 84/305 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- ADGRD1 | c.913C>A p.L305I | Missense Mutation (SNP) | VAF 10/312 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.07); called by muse, mutect2
- AMHR2 | c.584T>C p.V195A | Missense Mutation (SNP) | VAF 102/321 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD44 | c.420del p.R141Afs*9 | Frame Shift Del (DEL) | VAF 95/275 reads (35%) | called by mutect2, varscan2
- ANKRD63 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 92/253 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARFGAP3 | c.896dup p.N299Kfs*3 | Frame Shift Ins (INS) | VAF 44/159 reads (28%) | called by mutect2, varscan2
- ATP11C | c.2494G>A p.V832M | Missense Mutation (SNP) | VAF 62/108 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP5F1A | c.1226A>T p.N409I | Missense Mutation (SNP) | VAF 78/225 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ATP5PF | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ATP6V0B | c.414dup p.G139Wfs*10 | Frame Shift Ins (INS) | VAF 75/244 reads (31%) | called by mutect2, pindel, varscan2
- ATXN1 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 132/588 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- BCL11B | c.1742dup p.G582Rfs*8 (on ENST00000357195 / NM_001282237.2; = p.G511Rfs*8 on NM_022898.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 122/450 reads (27%) | called by pindel, varscan2
- BICDL2 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 100/319 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C2CD3 | c.1727dup p.R577Afs*26 | Frame Shift Ins (INS) | VAF 54/190 reads (28%) | called by mutect2, pindel, varscan2
- CA7 | c.449del p.L150Wfs*10 | Frame Shift Del (DEL) | VAF 75/299 reads (25%) | called by mutect2, pindel, varscan2
- CACNG2 | c.815C>T p.T272M | Missense Mutation (SNP) | VAF 128/433 reads (30%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CBX6 | c.879del p.K294Sfs*7 | Frame Shift Del (DEL) | VAF 178/588 reads (30%) | called by mutect2, pindel, varscan2
- CCDC88C | c.578T>C p.V193A | Missense Mutation (SNP) | VAF 121/374 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CCM2 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 70/205 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDC123 | c.650del p.F217Sfs*10 | Frame Shift Del (DEL) | VAF 34/169 reads (20%) | called by mutect2, pindel, varscan2
- CDKN1B | c.440A>G p.Q147R | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEP128 | c.2501A>G p.E834G | Missense Mutation (SNP) | VAF 66/228 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CFAP65 | c.3384G>A p.W1128* | Nonsense Mutation (SNP) | VAF 110/362 reads (30%) | called by muse, varscan2
- CIITA | c.492del p.T165Lfs*3 | Frame Shift Del (DEL) | VAF 82/291 reads (28%) | called by mutect2, pindel, varscan2
- CKM | c.785A>G p.E262G | Missense Mutation (SNP) | VAF 66/215 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CNTRL | c.3897del p.N1300Tfs*22 | Frame Shift Del (DEL) | VAF 63/270 reads (23%) | called by mutect2, pindel, varscan2
- COG6 | c.308G>T p.S103I | Missense Mutation (SNP) | VAF 63/196 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- CORIN | c.2207C>A p.S736Y | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- CROCC | c.5040G>T p.Q1680H | Missense Mutation (SNP) | VAF 100/292 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- CSMD3 | c.3598A>G p.I1200V (on ENST00000297405 / NM_001363185.1; = p.I1096V on NM_052900.3) | Missense Mutation (SNP) | VAF 92/293 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CSPG4 | c.6929C>T p.T2310I | Missense Mutation (SNP) | VAF 115/368 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CTBP2 | c.1061_1063del p.R354del | In Frame Del (DEL) | VAF 43/150 reads (29%) | called by mutect2, pindel, varscan2
- CTBS | c.988T>C p.Y330H | Missense Mutation (SNP) | VAF 73/189 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CUX2 | c.64A>G p.K22E | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); called by muse, mutect2
- DDX18 | c.1634A>G p.K545R | Missense Mutation (SNP) | VAF 77/189 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DEDD2 | c.957del p.R320Gfs*34 | Frame Shift Del (DEL) | VAF 78/285 reads (27%) | called by mutect2, pindel, varscan2
- DLD | c.674G>C p.G225A | Missense Mutation (SNP) | VAF 55/174 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAAF1 | c.1837A>G p.T613A | Missense Mutation (SNP) | VAF 77/264 reads (29%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- DNAJC6 | c.473dup p.N158Kfs*26 | Frame Shift Ins (INS) | VAF 46/194 reads (24%) | called by mutect2, pindel, varscan2
- DNHD1 | c.2020del p.H674Tfs*20 | Frame Shift Del (DEL) | VAF 93/320 reads (29%) | called by mutect2, pindel, varscan2
- DOCK4 | c.149del p.N50Tfs*15 | Frame Shift Del (DEL) | VAF 57/180 reads (32%) | called by mutect2, pindel, varscan2
- DPP9 | c.1339T>A p.C447S (on ENST00000598800; = p.C476S on NM_139159.5) | Missense Mutation (SNP) | VAF 100/312 reads (32%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DRG1 | c.803T>C p.V268A | Missense Mutation (SNP) | VAF 67/222 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- DYNLRB2 | c.176A>G p.D59G | Missense Mutation (SNP) | VAF 97/314 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.111); called by muse, mutect2
- ECPAS | c.158T>C p.M53T | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- EGR3 | c.946C>A p.R316S | Missense Mutation (SNP) | VAF 135/399 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EIF2B1 | c.70G>A p.V24M | Missense Mutation (SNP) | VAF 69/214 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- EXOC3L2 | c.95T>G p.V32G | Missense Mutation (SNP) | VAF 128/334 reads (38%) | SIFT tolerated, low confidence (0.5); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- EXOC6 | c.1825del p.I609Lfs*25 | Frame Shift Del (DEL) | VAF 78/244 reads (32%) | called by mutect2, pindel, varscan2
- F9 | c.618A>C p.E206D | Missense Mutation (SNP) | VAF 104/175 reads (59%) | SIFT tolerated (0.27); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FASTK | c.1526G>A p.G509D | Missense Mutation (SNP) | VAF 123/402 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBXO2 | c.820C>T p.Q274* | Nonsense Mutation (SNP) | VAF 157/462 reads (34%) | called by muse, mutect2, varscan2
- FBXO25 | c.1004T>A p.L335* | Nonsense Mutation (SNP) | VAF 65/179 reads (36%) | called by muse, mutect2, varscan2
- FBXO47 | c.949del p.R317Vfs*5 | Frame Shift Del (DEL) | VAF 59/192 reads (31%) | called by mutect2, pindel, varscan2
- FCER2 | c.565T>C p.Y189H | Missense Mutation (SNP) | VAF 116/359 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FHOD1 | c.165A>G p.I55M | Missense Mutation (SNP) | VAF 137/435 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- FNDC10 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 131/387 reads (34%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- FOCAD | c.4391G>T p.R1464I | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- FOXN4 | c.497dup p.F167Ifs*135 | Frame Shift Ins (INS) | VAF 63/280 reads (23%) | called by mutect2, pindel, varscan2
- FREM3 | c.1636G>A p.V546I | Missense Mutation (SNP) | VAF 101/301 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FRMD4A | c.2530G>A p.G844S | Missense Mutation (SNP) | VAF 104/382 reads (27%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, varscan2
- FSTL4 | c.2499del p.T834Pfs*59 | Frame Shift Del (DEL) | VAF 86/288 reads (30%) | called by mutect2, pindel, varscan2
- FTCD | c.259del p.A87Pfs*2 | Frame Shift Del (DEL) | VAF 101/381 reads (27%) | called by mutect2, pindel, varscan2
- GALNTL6 | c.1700_1702del p.K567del | In Frame Del (DEL) | VAF 74/274 reads (27%) | called by pindel, varscan2
- GET4 | c.949_950del p.S317Pfs*94 | Frame Shift Del (DEL) | VAF 64/299 reads (21%) | called by pindel, varscan2
- GFRA3 | c.992T>C p.L331P | Missense Mutation (SNP) | VAF 86/260 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- GOLGA3 | c.1637A>C p.Q546P | Missense Mutation (SNP) | VAF 91/291 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GOLGA6D | c.1960del p.Y654Mfs*3 | Frame Shift Del (DEL) | VAF 58/176 reads (33%) | called by mutect2, varscan2
- GPR135 | c.745del p.A249Rfs*66 | Frame Shift Del (DEL) | VAF 163/579 reads (28%) | called by mutect2, pindel, varscan2
- GPR26 | c.829del p.V277Cfs*33 | Frame Shift Del (DEL) | VAF 82/300 reads (27%) | called by mutect2, pindel, varscan2
- GPRIN1 | c.2856_2857insT p.G953Wfs*80 | Frame Shift Ins (INS) | VAF 155/538 reads (29%) | called by mutect2, pindel, varscan2
- GUF1 | c.537_539del p.F180del | In Frame Del (DEL) | VAF 56/180 reads (31%) | called by pindel, varscan2
- HAPLN4 | c.722del p.G241Afs*38 | Frame Shift Del (DEL) | VAF 167/562 reads (30%) | called by mutect2, pindel, varscan2
- HDLBP | c.1103_1104del p.S368Cfs*65 | Frame Shift Del (DEL) | VAF 53/199 reads (27%) | called by pindel, varscan2
- HECW1 | c.4079C>A p.A1360D | Missense Mutation (SNP) | VAF 63/215 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- HIPK3 | c.1300del p.C434Afs*13 | Frame Shift Del (DEL) | VAF 59/200 reads (30%) | called by mutect2, pindel, varscan2
- HOXD9 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 20/644 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.109); called by muse, mutect2
- HS3ST2 | c.377del p.G126Afs*39 | Frame Shift Del (DEL) | VAF 117/442 reads (26%) | called by mutect2, pindel, varscan2
- IGLON5 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 88/247 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- INSR | c.2801G>A p.G934D | Missense Mutation (SNP) | VAF 91/306 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITGB4 | c.4649A>C p.E1550A | Missense Mutation (SNP) | VAF 118/382 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITIH3 | c.2095G>T p.G699C | Missense Mutation (SNP) | VAF 86/178 reads (48%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- ITPR3 | c.6487G>A p.E2163K | Missense Mutation (SNP) | VAF 204/456 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- IWS1 | c.1905G>T p.E635D | Missense Mutation (SNP) | VAF 56/195 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- KANK1 | c.2975del p.K992Rfs*67 | Frame Shift Del (DEL) | VAF 38/161 reads (24%) | called by mutect2, pindel, varscan2
- KAT6A | c.2060G>A p.G687D | Missense Mutation (SNP) | VAF 87/288 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KAT7 | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 80/289 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KATNB1 | c.981dup p.N328Qfs*11 | Frame Shift Ins (INS) | VAF 107/393 reads (27%) | called by mutect2, pindel, varscan2
- KEL | c.1034del p.N345Tfs*11 | Frame Shift Del (DEL) | VAF 96/314 reads (31%) | called by mutect2, pindel, varscan2
- KIAA1671 | c.3383A>G p.D1128G | Missense Mutation (SNP) | VAF 102/341 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- KL | c.2973del p.F991Lfs*33 | Frame Shift Del (DEL) | VAF 43/207 reads (21%) | called by mutect2, pindel, varscan2
- KRBOX4 | c.502A>G p.K168E (on ENST00000344302 / NM_001129898.2; = p.K163E on NM_017776.2) | Missense Mutation (SNP) | VAF 82/120 reads (68%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRT78 | c.479C>A p.P160H | Missense Mutation (SNP) | VAF 124/372 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- KRTAP10-3 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 163/463 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- KRTAP4-4 | c.61T>C p.C21R | Missense Mutation (SNP) | VAF 142/444 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- LCP2 | c.1360del p.T454Qfs*73 | Frame Shift Del (DEL) | VAF 56/242 reads (23%) | called by mutect2, pindel, varscan2
- LDLRAD3 | c.361A>T p.K121* | Nonsense Mutation (SNP) | VAF 80/275 reads (29%) | called by muse, mutect2, varscan2
- LHX6 | c.833C>T p.T278M (on ENST00000373755 / NM_001242334.2; = p.T307M on NM_014368.5) | Missense Mutation (SNP) | VAF 161/467 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- LILRB4 | c.1073C>T p.A358V (on ENST00000391733 / NM_001278428.3; = p.A357V on NM_001278426.3) | Missense Mutation (SNP) | VAF 36/571 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.23); called by muse, mutect2
- LRFN1 | c.1187del p.P396Rfs*75 | Frame Shift Del (DEL) | VAF 123/431 reads (29%) | called by mutect2, pindel, varscan2
- LRRC53 | c.2991del p.K997Nfs*25 | Frame Shift Del (DEL) | VAF 57/179 reads (32%) | called by mutect2, varscan2
- LRTM2 | c.470del p.P157Lfs*26 | Frame Shift Del (DEL) | VAF 121/399 reads (30%) | called by mutect2, pindel, varscan2
- LTB4R | c.716T>C p.V239A | Missense Mutation (SNP) | VAF 145/471 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MAGEL2 | c.2968C>A p.P990T | Missense Mutation (SNP) | VAF 111/375 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MAP1B | c.6364C>T p.P2122S | Missense Mutation (SNP) | VAF 95/302 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- MAP3K21 | c.1127T>C p.L376P | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MARK3 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MCPH1 | c.1402del p.T468Pfs*32 | Frame Shift Del (DEL) | VAF 87/303 reads (29%) | called by mutect2, pindel, varscan2
- MDN1 | c.5820del p.G1941Efs*17 | Frame Shift Del (DEL) | VAF 149/393 reads (38%) | called by mutect2, pindel, varscan2
- MED19 | c.569del p.P190Qfs*103 (on ENST00000431606 / NM_001317078.3; = p.P190Qfs*18 on NM_153450.4) | Frame Shift Del (DEL) | VAF 37/124 reads (30%) | called by pindel, varscan2
- MEIS2 | c.145C>T p.Q49* (on ENST00000561208 / NM_170675.5; = p.Q36* on NM_002399.3) | Nonsense Mutation (SNP) | VAF 161/541 reads (30%) | called by muse, mutect2, varscan2
- MFAP4 | c.76C>T p.R26* | Nonsense Mutation (SNP) | VAF 103/342 reads (30%) | called by muse, mutect2, varscan2
- MIIP | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 110/373 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- MOAP1 | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 137/424 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MROH7 | c.1909C>A p.L637I | Missense Mutation (SNP) | VAF 80/235 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- MSANTD1 | c.671A>G p.E224G | Missense Mutation (SNP) | VAF 112/303 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- MYO15B | c.1501C>A p.L501M | Missense Mutation (SNP) | VAF 140/477 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- MYO1F | c.780G>A p.M260I | Missense Mutation (SNP) | VAF 71/190 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MYOF | c.2831dup p.D945Rfs*16 | Frame Shift Ins (INS) | VAF 74/310 reads (24%) | called by mutect2, pindel, varscan2
- MZF1 | c.216G>A p.W72* | Nonsense Mutation (SNP) | VAF 137/401 reads (34%) | called by muse, mutect2, varscan2
- NBN | c.1660G>A p.D554N | Missense Mutation (SNP) | VAF 69/219 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCF2 | c.539G>A p.G180D | Missense Mutation (SNP) | VAF 78/232 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- NDC1 | c.1822C>A p.L608I | Missense Mutation (SNP) | VAF 53/189 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- NDUFB2 | c.173G>A p.S58N | Missense Mutation (SNP) | VAF 103/343 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- NFE2L1 | c.485del p.P162Qfs*6 | Frame Shift Del (DEL) | VAF 49/196 reads (25%) | called by mutect2, pindel, varscan2
- NFYA | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 11/337 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- NIPAL4 | c.424G>T p.G142C | Missense Mutation (SNP) | VAF 85/269 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NME7 | c.1042dup p.T348Nfs*2 | Frame Shift Ins (INS) | VAF 62/236 reads (26%) | called by mutect2, pindel, varscan2
- NOD2 | c.351del p.K118Sfs*73 | Frame Shift Del (DEL) | VAF 110/424 reads (26%) | called by pindel, varscan2
- OPRD1 | c.983G>A p.C328Y | Missense Mutation (SNP) | VAF 168/464 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- OR1B1 | c.140T>C p.L47P | Missense Mutation (SNP) | VAF 82/273 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- OR2M3 | c.708A>T p.K236N | Missense Mutation (SNP) | VAF 114/295 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OR52N2 | c.519del p.N174Tfs*29 | Frame Shift Del (DEL) | VAF 102/353 reads (29%) | called by mutect2, pindel, varscan2
- OR6S1 | c.298A>T p.I100F | Missense Mutation (SNP) | VAF 81/242 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- OSBP2 | c.2537A>C p.E846A | Missense Mutation (SNP) | VAF 104/385 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- OVGP1 | c.730A>C p.N244H | Missense Mutation (SNP) | VAF 57/181 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- PBRM1 | c.3839_3840del p.S1280Cfs*2 (on ENST00000296302 / NM_001366071.2; = p.S1255Cfs*2 on NM_018313.5) | Frame Shift Del (DEL) | VAF 42/122 reads (34%) | called by pindel, varscan2
- PCDH15 | c.5520T>G p.C1840W | Missense Mutation (SNP) | VAF 70/207 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- PCDHB2 | c.983del p.G328Afs*12 | Frame Shift Del (DEL) | VAF 90/275 reads (33%) | called by mutect2, pindel, varscan2
- PCNT | c.9607G>A p.V3203I | Missense Mutation (SNP) | VAF 61/233 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- PES1 | c.358A>G p.I120V | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PHACTR1 | c.377G>T p.R126M | Missense Mutation (SNP) | VAF 158/313 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PHF19 | c.73del p.A25Pfs*12 | Frame Shift Del (DEL) | VAF 97/364 reads (27%) | called by mutect2, pindel, varscan2
- PHF20L1 | c.2522A>G p.N841S | Missense Mutation (SNP) | VAF 78/282 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PIGO | c.2521A>G p.T841A | Missense Mutation (SNP) | VAF 109/330 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3CD | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 155/449 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIMREG | c.731T>C p.V244A | Missense Mutation (SNP) | VAF 95/304 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKD1L2 | c.949dup p.E317Gfs*7 | Frame Shift Ins (INS) | VAF 93/276 reads (34%) | called by mutect2, pindel, varscan2
- PLCB3 | c.3155C>T p.A1052V | Missense Mutation (SNP) | VAF 116/364 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLEC | c.2990del p.P997Rfs*31 (on ENST00000322810 / NM_201380.4; = p.P887Rfs*31 on NM_000445.5) | Frame Shift Del (DEL) | VAF 111/404 reads (27%) | called by pindel, varscan2
- PPIG | c.1654A>G p.T552A | Missense Mutation (SNP) | VAF 103/300 reads (34%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP1R17 | c.326T>C p.L109P | Missense Mutation (SNP) | VAF 89/322 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PPP1R3E | c.676C>A p.P226T | Missense Mutation (SNP) | VAF 175/629 reads (28%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- PPP2R5D | c.231del p.Q79Rfs*28 | Frame Shift Del (DEL) | VAF 235/557 reads (42%) | called by mutect2, pindel, varscan2
- PRKCA | c.788T>C p.V263A | Missense Mutation (SNP) | VAF 84/209 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- PRPF4 | c.1103A>G p.Y368C (on ENST00000374198 / NM_001322267.2; = p.Y369C on NM_004697.5) | Missense Mutation (SNP) | VAF 69/229 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PRRT2 | c.776del p.G259Vfs*54 | Frame Shift Del (DEL) | VAF 137/465 reads (29%) | called by mutect2, pindel, varscan2
- PSIP1 | c.1384_1387del p.K462Gfs*6 | Frame Shift Del (DEL) | VAF 61/211 reads (29%) | called by mutect2, pindel, varscan2
- PSRC1 | c.844G>A p.A282T (on ENST00000409138 / NM_001363309.1; = p.A252T on NM_032636.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 149/424 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- PTCHD3 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 144/484 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PTGFRN | c.584G>A p.S195N | Missense Mutation (SNP) | VAF 177/552 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PUS7 | c.96del p.K32Nfs*9 | Frame Shift Del (DEL) | VAF 80/271 reads (30%) | called by mutect2, pindel, varscan2
- PWWP3A | c.691A>T p.N231Y (on ENST00000627377; = p.N230Y on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 116/379 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- RAP2C | c.479T>G p.I160S | Missense Mutation (SNP) | VAF 120/171 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- RERE | c.1246_1248del p.F416del | In Frame Del (DEL) | VAF 54/214 reads (25%) | called by pindel, varscan2
- RGL2 | c.2279del p.G760Afs*37 | Frame Shift Del (DEL) | VAF 323/768 reads (42%) | called by mutect2, pindel, varscan2
- ROGDI | c.139_140del p.L47Afs*6 | Frame Shift Del (DEL) | VAF 118/495 reads (24%) | called by pindel, varscan2
- SALL3 | c.610del p.L204* | Frame Shift Del (DEL) | VAF 166/605 reads (27%) | called by mutect2, pindel, varscan2
- SCAF8 | c.529C>A p.P177T | Missense Mutation (SNP) | VAF 64/303 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SETX | c.6621T>A p.D2207E | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SEZ6L | c.2993A>G p.Y998C | Missense Mutation (SNP) | VAF 73/219 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SFPQ | c.1770G>C p.R590S | Missense Mutation (SNP) | VAF 58/245 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SGCA | c.303G>T p.Q101H | Missense Mutation (SNP) | VAF 82/232 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SGTA | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 94/265 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, varscan2
- SHOC1 | c.1624_1627del p.N542Vfs*12 | Frame Shift Del (DEL) | VAF 37/160 reads (23%) | called by mutect2, pindel, varscan2
- SLC10A6 | c.896T>C p.I299T | Missense Mutation (SNP) | VAF 68/205 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SLC11A2 | c.1353del p.T452Lfs*10 (on ENST00000394904 / NM_001379455.1; = p.T423Lfs*10 on NM_000617.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 64/265 reads (24%) | called by mutect2, pindel, varscan2
- SLC12A4 | c.3230G>A p.G1077D | Missense Mutation (SNP) | VAF 85/289 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC16A2 | c.143del p.P48Rfs*36 | Frame Shift Del (DEL) | VAF 205/386 reads (53%) | called by mutect2, pindel, varscan2
- SLC38A1 | c.1387G>C p.V463L | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.048); called by muse, varscan2
- SLC6A2 | c.1226del p.F409Sfs*30 | Frame Shift Del (DEL) | VAF 65/286 reads (23%) | called by mutect2, pindel, varscan2
- SNAPC4 | c.257G>A p.C86Y | Missense Mutation (SNP) | VAF 109/344 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNRK | c.2264C>T p.A755V | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SNX17 | c.1079A>G p.Q360R | Missense Mutation (SNP) | VAF 83/233 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SOCS1 | c.594dup p.V199Rfs*54 | Frame Shift Ins (INS) | VAF 105/359 reads (29%) | called by mutect2, pindel, varscan2
- SOX13 | c.969del p.S324Afs*82 | Frame Shift Del (DEL) | VAF 132/364 reads (36%) | called by mutect2, varscan2
- SPINT1 | c.707T>C p.V236A | Missense Mutation (SNP) | VAF 93/326 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPTY2D1 | c.648del p.K216Nfs*254 | Frame Shift Del (DEL) | VAF 81/252 reads (32%) | called by mutect2, pindel, varscan2
- SSU72P8 | c.556del p.S186Afs*? | Frame Shift Del (DEL) | VAF 81/327 reads (25%) | called by mutect2, pindel, varscan2
- STIM1 | c.1820G>A p.G607D | Missense Mutation (SNP) | VAF 46/468 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.992); called by muse, mutect2
- STXBP5 | c.2504dup p.E836Rfs*41 (on ENST00000321680 / NM_001127715.2; = p.E800Rfs*41 on NM_139244.4) | Frame Shift Ins (INS) | VAF 155/402 reads (39%) | called by mutect2, pindel, varscan2
- SYCP2L | c.2145del p.K715Nfs*27 | Frame Shift Del (DEL) | VAF 87/245 reads (36%) | called by mutect2, pindel, varscan2
- SYNGAP1 | c.254del p.T85Kfs*49 | Frame Shift Del (DEL) | VAF 243/596 reads (41%) | called by mutect2, pindel, varscan2
- SYNPO | c.1429C>A p.P477T (on ENST00000394243 / NM_001166208.2; = p.P233T on NM_007286.6) | Missense Mutation (SNP) | VAF 132/410 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TBC1D30 | c.1187T>C p.M396T (on ENST00000542120; = p.M233T on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/293 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TBL1X | c.253A>G p.I85V | Missense Mutation (SNP) | VAF 102/172 reads (59%) | SIFT tolerated (0.4); PolyPhen benign (0.175); called by muse, varscan2
- TBXT | c.735del p.W246Gfs*37 | Frame Shift Del (DEL) | VAF 49/302 reads (16%) | called by mutect2, pindel, varscan2
- TCF20 | c.5173del p.Y1725Ifs*157 | Frame Shift Del (DEL) | VAF 154/505 reads (30%) | called by mutect2, pindel, varscan2
- TCP1 | c.308del p.N103Mfs*5 | Frame Shift Del (DEL) | VAF 46/252 reads (18%) | called by mutect2, pindel, varscan2
- TDRD15 | c.4119del p.F1373Lfs*3 | Frame Shift Del (DEL) | VAF 59/191 reads (31%) | called by mutect2, pindel, varscan2
- THAP4 | c.1720_1722del p.K574del | In Frame Del (DEL) | VAF 55/207 reads (27%) | called by pindel, varscan2
- THG1L | c.331T>A p.F111I | Missense Mutation (SNP) | VAF 64/209 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- TMEM132D | c.618del p.T207Rfs*75 | Frame Shift Del (DEL) | VAF 161/584 reads (28%) | called by mutect2, pindel, varscan2
- TMEM151B | c.1505C>T p.T502M | Missense Mutation (SNP) | VAF 198/690 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- TOP1 | c.1852_1855del p.S618Ifs*26 | Frame Shift Del (DEL) | VAF 45/184 reads (24%) | called by mutect2, pindel, varscan2
- TRAF4 | c.533G>T p.R178L | Missense Mutation (SNP) | VAF 140/411 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2
- TSPAN14 | c.280-1G>C p.X94_splice | Splice Site (SNP) | VAF 74/186 reads (40%) | called by muse, mutect2, varscan2
- TSPAN3 | c.631C>T p.H211Y | Missense Mutation (SNP) | VAF 36/269 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTLL3 | c.2231G>A p.G744D | Missense Mutation (SNP) | VAF 105/354 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- TTN | c.47178A>G p.L15726= (on ENST00000591111; = p.L8302= on NM_003319.4) | Splice Region (SNP) | VAF 39/126 reads (31%) | called by muse, mutect2, varscan2
- TTPAL | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 60/215 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBE4A | c.2791A>G p.T931A (on ENST00000252108 / NM_001204077.2; = p.T938A on NM_004788.4) | Missense Mutation (SNP) | VAF 72/215 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UCHL5 | c.662T>C p.M221T | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- UFM1 | c.226A>G p.I76V | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- USP24 | c.7256T>C p.V2419A | Missense Mutation (SNP) | VAF 67/215 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- USP9X | c.5694T>G p.Y1898* | Nonsense Mutation (SNP) | VAF 17/188 reads (9%) | called by muse, mutect2
- USP9Y | c.3611A>G p.Q1204R | Missense Mutation (SNP) | VAF 64/106 reads (60%) | SIFT tolerated (0.33); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- UTRN | c.7264del p.T2422Hfs*35 | Frame Shift Del (DEL) | VAF 49/238 reads (21%) | called by mutect2, pindel, varscan2
- WNK4 | c.1742C>T p.S581L | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- WNT2B | c.1031A>G p.Y344C (on ENST00000369684 / NM_024494.3; = p.Y325C on NM_004185.4) | Missense Mutation (SNP) | VAF 119/340 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 170/536 reads (32%) | called by mutect2, pindel, varscan2
- ZBTB4 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 140/428 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- ZNF135 | c.732T>A p.C244* (on ENST00000313434 / NM_001289401.2; = p.C256* on NM_003436.4) | Nonsense Mutation (SNP) | VAF 104/344 reads (30%) | called by muse, mutect2, varscan2
- ZNF165 | c.616A>G p.R206G | Missense Mutation (SNP) | VAF 61/248 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF280A | c.926del p.N309Ifs*5 | Frame Shift Del (DEL) | VAF 116/389 reads (30%) | called by mutect2, pindel, varscan2
- ZNF347 | c.1247T>C p.L416P | Missense Mutation (SNP) | VAF 114/364 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF423 | c.2816dup p.C940Vfs*35 (on ENST00000563137 / NM_001379286.1; = p.C932Vfs*35 on NM_015069.4) | Frame Shift Ins (INS) | VAF 84/318 reads (26%) | called by pindel, varscan2
- ZNF629 | c.506A>C p.Q169P | Missense Mutation (SNP) | VAF 154/479 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF730 | c.755G>C p.G252A | Missense Mutation (SNP) | VAF 80/237 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- ZNF793 | c.776A>G p.D259G | Missense Mutation (SNP) | VAF 104/302 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- ZXDA | c.2025_2028del p.F676Lfs*13 | Frame Shift Del (DEL) | VAF 15/28 reads (54%) | called by mutect2, varscan2
- ABCA4 | c.3567A>G p.P1189= | Silent (SNP) | VAF 106/299 reads (35%) | called by muse, mutect2, varscan2
- ABCD3 | c.756T>C p.G252= | Silent (SNP) | VAF 74/264 reads (28%) | called by muse, mutect2, varscan2
- ACIN1 | c.2475C>T p.S825= | Silent (SNP) | VAF 67/216 reads (31%) | catalogued as rs753592310; called by muse, mutect2, varscan2
- ADAMTS9 | c.4614C>T p.N1538= | Silent (SNP) | VAF 120/219 reads (55%) | called by muse, mutect2, varscan2
- ADGRD1 | c.2163G>A p.L721= | Silent (SNP) | VAF 116/319 reads (36%) | called by muse, mutect2, varscan2
- AGRN | c.5775C>T p.D1925= | Silent (SNP) | VAF 133/430 reads (31%) | catalogued as rs375797607; ClinVar: likely benign; called by muse, mutect2, varscan2
- AHNAK2 | c.10252C>T p.L3418= | Silent (SNP) | VAF 134/410 reads (33%) | called by muse, mutect2, varscan2
- AMER3 | c.2064C>T p.N688= | Silent (SNP) | VAF 128/404 reads (32%) | catalogued as rs763951703, COSV58467051; called by muse, mutect2, varscan2
- ANKRD24 | c.3036G>A p.E1012= | Silent (SNP) | VAF 80/286 reads (28%) | called by muse, mutect2, varscan2
- ANKS6 | c.627A>G p.L209= | Silent (SNP) | VAF 146/430 reads (34%) | called by muse, mutect2, varscan2
- AOC3 | c.70C>T p.L24= | Silent (SNP) | VAF 121/378 reads (32%) | catalogued as COSV53828806; called by muse, mutect2, varscan2
- AOC3 | c.705C>T p.G235= | Silent (SNP) | VAF 106/341 reads (31%) | catalogued as rs761064515, COSV53826309; called by muse, mutect2, varscan2
- ARHGAP21 | c.2949T>C p.S983= | Silent (SNP) | VAF 89/285 reads (31%) | called by muse, mutect2, varscan2
- ARHGAP39 | c.2448G>A p.P816= | Silent (SNP) | VAF 142/401 reads (35%) | catalogued as rs762965371; called by muse, mutect2, varscan2
- ATCAY | c.282C>T p.N94= | Silent (SNP) | VAF 87/311 reads (28%) | catalogued as rs549326005, COSV56655220; called by muse, mutect2, varscan2
- ATP12A | c.2805G>A p.T935= | Silent (SNP) | VAF 85/312 reads (27%) | catalogued as rs146443073; called by muse, mutect2, varscan2
- ATP2B3 | c.2976C>T p.G992= | Silent (SNP) | VAF 94/152 reads (62%) | catalogued as rs1369968545, COSV54862278; called by muse, mutect2, varscan2
- B3GALT4 | c.192C>T p.C64= | Silent (SNP) | VAF 396/795 reads (50%) | called by muse, mutect2, varscan2
- B3GNT9 | c.219G>A p.P73= | Silent (SNP) | VAF 136/499 reads (27%) | catalogued as rs1211258117; called by muse, mutect2, varscan2
- BEST4 | c.1266C>A p.S422= | Silent (SNP) | VAF 170/569 reads (30%) | called by muse, mutect2, varscan2
- BNC2 | c.3018C>T p.A1006= | Silent (SNP) | VAF 130/366 reads (36%) | catalogued as rs754154261; called by muse, mutect2, varscan2
- C1QB | c.264C>T p.G88= | Silent (SNP) | VAF 94/298 reads (32%) | called by muse, mutect2, varscan2
- C1QB | c.675C>T p.T225= | Silent (SNP) | VAF 92/311 reads (30%) | catalogued as rs146518300; called by muse, mutect2, varscan2
- C1orf162 | c.396C>T p.S132= | Silent (SNP) | VAF 66/303 reads (22%) | called by muse, mutect2, varscan2
- C1orf68 | c.678C>T p.C226= | Silent (SNP) | VAF 33/377 reads (9%) | called by muse, mutect2
- CACNA1G | c.7113C>T p.D2371= | Silent (SNP) | VAF 64/235 reads (27%) | catalogued as rs369105422; called by muse, mutect2, varscan2
- CAMTA1 | c.2508G>A p.S836= | Silent (SNP) | VAF 150/464 reads (32%) | catalogued as rs750794977; called by muse, mutect2, varscan2
- CAPRIN2 | c.897A>G p.K299= | Silent (SNP) | VAF 49/143 reads (34%) | catalogued as COSV51834009; called by muse, mutect2, varscan2
- CDH2 | c.480C>T p.D160= | Silent (SNP) | VAF 70/294 reads (24%) | called by muse, mutect2, varscan2
- CEACAM3 | c.288C>T p.S96= | Silent (SNP) | VAF 83/210 reads (40%) | catalogued as rs782428338; called by muse, varscan2
- CELSR1 | c.423C>T p.A141= | Silent (SNP) | VAF 184/489 reads (38%) | catalogued as rs1208309080; called by muse, mutect2, varscan2
- CKMT2 | c.111G>T p.V37= | Silent (SNP) | VAF 80/281 reads (28%) | called by muse, mutect2, varscan2
- CLEC10A | c.345G>A p.R115= | Silent (SNP) | VAF 63/233 reads (27%) | called by muse, mutect2, varscan2
- CNTNAP1 | c.1440C>A p.T480= | Silent (SNP) | VAF 80/235 reads (34%) | called by muse, mutect2, varscan2
- COMP | c.897G>A p.G299= | Silent (SNP) | VAF 85/290 reads (29%) | called by muse, mutect2, varscan2
- CPNE7 | c.1431G>A p.L477= | Silent (SNP) | VAF 133/446 reads (30%) | catalogued as rs1406347128; called by muse, mutect2, varscan2
- CYP1A1 | c.867T>C p.C289= | Silent (SNP) | VAF 81/266 reads (30%) | catalogued as rs1056775144; called by muse, mutect2, varscan2
- DACT1 | c.1731C>T p.G577= | Silent (SNP) | VAF 110/369 reads (30%) | catalogued as rs775086704, COSV60021213; called by muse, mutect2, varscan2
- DCP1B | c.51C>T p.S17= | Silent (SNP) | VAF 105/362 reads (29%) | catalogued as rs1469982360; called by muse, mutect2, varscan2
- DEFB113 | c.189G>A p.A63= | Silent (SNP) | VAF 65/324 reads (20%) | catalogued as rs779312079, COSV100435452; called by muse, mutect2, varscan2
- DENND10 | c.105G>A p.T35= | Silent (SNP) | VAF 69/275 reads (25%) | catalogued as rs746252091; called by muse, mutect2, varscan2
- DIDO1 | c.4311G>A p.A1437= | Silent (SNP) | VAF 155/428 reads (36%) | called by muse, mutect2, varscan2
- DIP2C | c.4662C>T p.Y1554= | Silent (SNP) | VAF 66/203 reads (33%) | called by muse, mutect2, varscan2
- DIRAS2 | c.537C>T p.D179= | Silent (SNP) | VAF 89/262 reads (34%) | catalogued as COSV65370017; called by muse, mutect2, varscan2
- DLL3 | c.1677G>A p.S559= | Silent (SNP) | VAF 40/165 reads (24%) | catalogued as rs772924663; called by muse, mutect2, varscan2
- DMXL2 | c.8163T>C p.T2721= | Silent (SNP) | VAF 72/224 reads (32%) | called by muse, mutect2, varscan2
- DMXL2 | c.6639G>A p.A2213= | Silent (SNP) | VAF 96/287 reads (33%) | catalogued as rs185024518, COSV51845622; called by muse, mutect2, varscan2
- DNHD1 | c.13671C>A p.R4557= | Silent (SNP) | VAF 129/449 reads (29%) | called by muse, mutect2, varscan2
- DPY30 | c.99T>C p.N33= | Silent (SNP) | VAF 60/173 reads (35%) | called by muse, mutect2, varscan2
- DSPP | c.3135C>T p.S1045= | Silent (SNP) | VAF 128/366 reads (35%) | catalogued as rs1302769818; called by muse, mutect2, varscan2
- ELMO1 | c.15G>A p.A5= | Silent (SNP) | VAF 67/214 reads (31%) | catalogued as rs763975766; called by muse, mutect2, varscan2
- EMILIN3 | c.2124G>A p.A708= | Silent (SNP) | VAF 137/456 reads (30%) | catalogued as rs376937470; called by muse, mutect2, varscan2
- ENTR1 | c.1035C>T p.V345= (on ENST00000357365 / NM_001039707.2; = p.V322= on NM_006643.4) | Silent (SNP) | VAF 67/214 reads (31%) | catalogued as rs1238219904; called by muse, mutect2, varscan2
- EPHA7 | c.663T>C p.G221= | Silent (SNP) | VAF 179/369 reads (49%) | called by muse, mutect2, varscan2
- FAM186B | c.2211G>A p.T737= | Silent (SNP) | VAF 68/230 reads (30%) | catalogued as rs555752465; called by muse, mutect2, varscan2
- FASTKD1 | c.957T>C p.P319= | Silent (SNP) | VAF 48/132 reads (36%) | called by muse, mutect2, varscan2
- FBXL18 | c.1662C>T p.G554= | Silent (SNP) | VAF 109/367 reads (30%) | called by muse, mutect2, varscan2
- FLNC | c.1365G>A p.A455= | Silent (SNP) | VAF 131/383 reads (34%) | catalogued as rs377345122; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLOT1 | c.468T>C p.D156= | Silent (SNP) | VAF 174/335 reads (52%) | called by muse, mutect2, varscan2
- FOLR2 | c.591C>T p.S197= | Silent (SNP) | VAF 105/359 reads (29%) | called by muse, mutect2, varscan2
- FOXE3 | c.543G>A p.G181= | Silent (SNP) | VAF 69/348 reads (20%) | catalogued as rs765016567; called by muse, mutect2, varscan2
- FRMPD2 | c.987G>A p.S329= | Silent (SNP) | VAF 76/267 reads (28%) | catalogued as rs747340642; called by muse, mutect2, varscan2
- GCNA | c.570C>T p.D190= | Silent (SNP) | VAF 151/229 reads (66%) | catalogued as rs1437621461; called by muse, mutect2, varscan2
- GFRA1 | c.87C>T p.C29= | Silent (SNP) | VAF 101/282 reads (36%) | called by muse, varscan2
- GFUS | c.483C>T p.Y161= | Silent (SNP) | VAF 89/339 reads (26%) | catalogued as rs759092194, COSV55306190; called by muse, mutect2, varscan2
- GIMAP6 | c.357C>T p.S119= | Silent (SNP) | VAF 107/374 reads (29%) | catalogued as rs753596703, COSV61033577; called by muse, mutect2, varscan2
- GLIS2 | c.1509G>A p.A503= | Silent (SNP) | VAF 170/505 reads (34%) | catalogued as rs771159639; ClinVar: likely benign; called by muse, mutect2
- GNL1 | c.753C>T p.V251= | Silent (SNP) | VAF 199/402 reads (50%) | catalogued as rs373106261; called by muse, mutect2, varscan2
- GOLM2 | c.1155C>T p.N385= | Silent (SNP) | VAF 65/237 reads (27%) | catalogued as rs763167324; called by muse, mutect2, varscan2
- GPATCH2L | c.186C>T p.S62= | Silent (SNP) | VAF 96/312 reads (31%) | catalogued as rs1168941242; called by muse, mutect2, varscan2
- GPR27 | c.741C>T p.G247= | Silent (SNP) | VAF 74/184 reads (40%) | catalogued as rs1444382669; called by muse, mutect2, varscan2
- GPR50 | c.99C>T p.C33= | Silent (SNP) | VAF 108/188 reads (57%) | catalogued as rs756964167, COSV54439645; called by muse, mutect2, varscan2
- GPR78 | c.879G>A p.T293= | Silent (SNP) | VAF 125/377 reads (33%) | catalogued as rs546309729, COSV66762596; called by muse, mutect2, varscan2
- GRIN3B | c.258G>A p.S86= | Silent (SNP) | VAF 149/419 reads (36%) | catalogued as rs1297838787; called by muse, mutect2, varscan2
- HOXD12 | c.192G>A p.A64= | Silent (SNP) | VAF 163/507 reads (32%) | called by muse, mutect2, varscan2
- HRNR | c.3444C>T p.S1148= | Silent (SNP) | VAF 56/1406 reads (4%) | catalogued as rs759603229; called by muse, mutect2
- HTR1A | c.1107C>T p.P369= | Silent (SNP) | VAF 153/436 reads (35%) | called by muse, mutect2, varscan2
- HTR5A | c.309C>T p.S103= | Silent (SNP) | VAF 125/413 reads (30%) | catalogued as COSV55280602; called by muse, mutect2, varscan2
- IGSF1 | c.3945C>T p.G1315= | Silent (SNP) | VAF 94/143 reads (66%) | called by muse, mutect2, varscan2
- IGSF10 | c.7551T>C p.I2517= | Silent (SNP) | VAF 81/270 reads (30%) | called by muse, mutect2, varscan2
- IL10RA | c.1431C>T p.F477= | Silent (SNP) | VAF 130/366 reads (36%) | catalogued as rs1334671007; called by muse, mutect2, varscan2
- ILVBL | c.1869G>A p.T623= | Silent (SNP) | VAF 76/262 reads (29%) | catalogued as rs1031124546; called by muse, mutect2, varscan2
- ING2 | c.249G>A p.Q83= | Silent (SNP) | VAF 56/218 reads (26%) | called by muse, mutect2, varscan2
- ITGA9 | c.1437G>A p.A479= | Silent (SNP) | VAF 97/229 reads (42%) | catalogued as rs201894427; called by muse, mutect2, varscan2
- KCNA3 | c.1674G>A p.T558= | Silent (SNP) | VAF 94/315 reads (30%) | catalogued as rs1466966510, COSV63902092, COSV63902162; called by muse, mutect2, varscan2
- KIAA0319L | c.2997C>T p.S999= | Silent (SNP) | VAF 78/271 reads (29%) | catalogued as rs376088664; called by muse, mutect2, varscan2
- KIAA1109 | c.2115C>A p.P705= | Silent (SNP) | VAF 70/254 reads (28%) | called by muse, mutect2, varscan2
- KIF22 | c.402G>A p.T134= | Silent (SNP) | VAF 80/248 reads (32%) | catalogued as rs1567358371, COSV50715900; called by muse, mutect2, varscan2
- KMT2A | c.2319G>A p.P773= | Silent (SNP) | VAF 96/253 reads (38%) | catalogued as rs147308365; called by muse, mutect2, varscan2
- KRTAP1-5 | c.468G>A p.P156= | Silent (SNP) | VAF 169/537 reads (31%) | catalogued as rs534171351, COSV62624057; called by muse, mutect2, varscan2
- LACTB2 | c.516G>A p.T172= | Silent (SNP) | VAF 75/207 reads (36%) | catalogued as rs767793256, COSV52567012; called by muse, mutect2, varscan2
- LANCL2 | c.1218C>T p.H406= | Silent (SNP) | VAF 67/245 reads (27%) | catalogued as rs200759229, COSV54647595; called by muse, mutect2, varscan2
- LCP2 | c.477C>A p.S159= | Silent (SNP) | VAF 79/283 reads (28%) | called by muse, mutect2, varscan2
- LDHD | c.477C>T p.G159= | Silent (SNP) | VAF 93/294 reads (32%) | called by muse, mutect2, varscan2
- LRP5 | c.3984C>T p.D1328= | Silent (SNP) | VAF 90/261 reads (34%) | catalogued as rs555253491; called by muse, mutect2, varscan2
- LYPD4 | c.192G>A p.T64= | Silent (SNP) | VAF 56/163 reads (34%) | catalogued as rs781940438; called by muse, mutect2, varscan2
- MACF1 | c.9705A>G p.A3235= | Silent (SNP) | VAF 81/204 reads (40%) | called by muse, mutect2, varscan2
- MAP1A | c.7395C>T p.D2465= | Silent (SNP) | VAF 101/330 reads (31%) | called by muse, mutect2, varscan2
- MBOAT7 | c.582C>T p.R194= | Silent (SNP) | VAF 162/524 reads (31%) | catalogued as rs1267494778; called by muse, mutect2, varscan2
- MMP24 | c.990C>T p.A330= | Silent (SNP) | VAF 86/268 reads (32%) | catalogued as rs747880766; called by muse, mutect2, varscan2
- MRGPRX4 | c.420G>A p.A140= | Silent (SNP) | VAF 116/361 reads (32%) | catalogued as rs776405349, COSV58590750; called by muse, mutect2, varscan2
- MX2 | c.2106G>A p.A702= | Silent (SNP) | VAF 66/223 reads (30%) | catalogued as rs143528488; called by muse, mutect2, varscan2
- MYO10 | c.3912G>A p.V1304= | Silent (SNP) | VAF 60/222 reads (27%) | called by muse, mutect2, varscan2
- MYOF | c.2931T>C p.D977= | Silent (SNP) | VAF 86/274 reads (31%) | catalogued as rs774148211; called by muse, mutect2, varscan2
- MYOM2 | c.942C>T p.A314= | Silent (SNP) | VAF 92/287 reads (32%) | catalogued as rs144856803; called by muse, mutect2, varscan2
- MYOZ1 | c.63A>G p.E21= | Silent (SNP) | VAF 56/182 reads (31%) | called by muse, mutect2, varscan2
- NCOR2 | c.5373G>A p.T1791= | Silent (SNP) | VAF 96/338 reads (28%) | catalogued as rs370212615; called by muse, mutect2, varscan2
- NHLRC1 | c.51C>T p.R17= | Silent (SNP) | VAF 162/596 reads (27%) | catalogued as rs1282199944; called by muse, mutect2, varscan2
- NISCH | c.2667C>A p.A889= | Silent (SNP) | VAF 169/323 reads (52%) | catalogued as rs370031657; called by muse, mutect2, varscan2
- NKX6-1 | c.387G>A p.S129= | Silent (SNP) | VAF 130/491 reads (26%) | called by muse, varscan2
- NOTCH4 | c.1545C>T p.N515= | Silent (SNP) | VAF 223/470 reads (47%) | catalogued as rs760447830; called by muse, mutect2, varscan2
- OOEP | c.51G>A p.P17= | Silent (SNP) | VAF 204/446 reads (46%) | catalogued as rs375221508; called by muse, mutect2, varscan2
- OPLAH | c.1053C>T p.T351= | Silent (SNP) | VAF 97/408 reads (24%) | catalogued as rs374660106; called by muse, mutect2, varscan2
- OR8J2 | c.717C>G p.S239= | Silent (SNP) | VAF 61/199 reads (31%) | called by muse, mutect2, varscan2
- P2RY8 | c.477G>A p.A159= | Silent (SNP) | VAF 175/539 reads (32%) | called by muse, mutect2, varscan2
- PABPC5 | c.207C>T p.P69= | Silent (SNP) | VAF 146/230 reads (63%) | catalogued as COSV100442142; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.270G>A p.E90= (on ENST00000374531 / NM_001037293.2; = p.E88= on NM_007203.5) | Silent (SNP) | VAF 53/179 reads (30%) | catalogued as COSV100092296; called by muse, mutect2, varscan2
- PAPLN | c.531T>C p.G177= | Silent (SNP) | VAF 127/363 reads (35%) | called by muse, mutect2, varscan2
- PATZ1 | c.1902C>G p.G634= | Silent (SNP) | VAF 95/366 reads (26%) | called by muse, mutect2, varscan2
- PCDH8 | c.1533G>A p.P511= | Silent (SNP) | VAF 152/520 reads (29%) | called by muse, mutect2, varscan2
- PCDHB11 | c.1707C>T p.S569= | Silent (SNP) | VAF 114/628 reads (18%) | catalogued as rs782518088; called by muse, mutect2, varscan2
- PCDHB12 | c.1134C>T p.N378= | Silent (SNP) | VAF 83/261 reads (32%) | catalogued as COSV99506684; called by muse, mutect2, varscan2
- PCDHB15 | c.1341C>T p.N447= | Silent (SNP) | VAF 133/395 reads (34%) | catalogued as COSV51277803; called by muse, mutect2, varscan2
- PCDHGA2 | c.1947C>T p.H649= | Silent (SNP) | VAF 188/627 reads (30%) | catalogued as rs769573354, COSV53965443; called by muse, mutect2, varscan2
- PGAP6 | c.312C>T p.S104= | Silent (SNP) | VAF 99/293 reads (34%) | catalogued as rs531846854; called by muse, mutect2, varscan2
- PHYHIP | c.540C>T p.H180= | Silent (SNP) | VAF 51/393 reads (13%) | catalogued as rs552436087; called by muse, mutect2, varscan2
- PLCH2 | c.339C>T p.D113= | Silent (SNP) | VAF 145/405 reads (36%) | catalogued as rs751401229, COSV53939163; called by muse, mutect2, varscan2
- PLPPR3 | c.1368A>G p.E456= (on ENST00000520876 / NM_001270366.2; = p.E484= on NM_024888.2) | Silent (SNP) | VAF 135/460 reads (29%) | called by mutect2, varscan2
- PNPT1 | c.1077C>T p.C359= | Silent (SNP) | VAF 28/142 reads (20%) | catalogued as rs745772657, COSV53178898; called by muse, mutect2, varscan2
- PRDM15 | c.1644C>T p.H548= | Silent (SNP) | VAF 100/345 reads (29%) | catalogued as rs767871819; called by muse, mutect2, varscan2
- PROS1 | c.27G>A p.G9= | Silent (SNP) | VAF 97/377 reads (26%) | called by muse, mutect2, varscan2
- PRSS48 | c.294C>T p.Y98= | Silent (SNP) | VAF 80/270 reads (30%) | catalogued as rs199896407; called by muse, mutect2, varscan2
- PSG8 | c.927A>G p.Q309= | Silent (SNP) | VAF 101/324 reads (31%) | catalogued as rs1350030021; called by muse, mutect2, varscan2
- PTPRD | c.3531C>T p.R1177= | Silent (SNP) | VAF 46/155 reads (30%) | catalogued as rs1372087072, COSV61968730; called by muse, mutect2, varscan2
- PTPRS | c.2409C>T p.T803= | Silent (SNP) | VAF 88/265 reads (33%) | catalogued as rs1183817023, COSV53639196; called by muse, mutect2, varscan2
- PUF60 | c.492C>T p.S164= (on ENST00000526683 / NM_001362896.2; = p.S147= on NM_014281.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 50/347 reads (14%) | catalogued as rs376322427; called by muse, mutect2, varscan2
- QSOX2 | c.960G>A p.S320= | Silent (SNP) | VAF 55/173 reads (32%) | catalogued as rs770914309; called by muse, mutect2, varscan2
- RAB5C | c.63A>G p.Q21= | Silent (SNP) | VAF 124/388 reads (32%) | catalogued as rs768234973; called by muse, mutect2, varscan2
- RAPGEF2 | c.2013G>A p.Q671= | Silent (SNP) | VAF 59/198 reads (30%) | called by muse, mutect2, varscan2
- RAPGEF6 | c.4527A>G p.P1509= | Silent (SNP) | VAF 74/241 reads (31%) | catalogued as rs1034283416; called by muse, mutect2, varscan2
- RASAL3 | c.1977C>T p.A659= | Silent (SNP) | VAF 49/202 reads (24%) | called by muse, mutect2, varscan2
- RBBP6 | c.2058T>G p.S686= | Silent (SNP) | VAF 34/106 reads (32%) | called by muse, mutect2, varscan2
- RGS20 | c.378C>T p.R126= | Silent (SNP) | VAF 141/510 reads (28%) | catalogued as rs1359389006; called by muse, mutect2, varscan2
- RNF151 | c.522C>T p.R174= | Silent (SNP) | VAF 148/450 reads (33%) | called by muse, mutect2, varscan2
- RNF19A | c.768G>A p.Q256= | Silent (SNP) | VAF 135/339 reads (40%) | catalogued as COSV61992700; called by muse, mutect2, varscan2
- RP1 | c.5676T>C p.P1892= | Silent (SNP) | VAF 83/287 reads (29%) | called by muse, mutect2, varscan2
- RREB1 | c.2601C>T p.N867= | Silent (SNP) | VAF 269/577 reads (47%) | catalogued as rs769736395, COSV58559861; called by muse, mutect2, varscan2
- RREB1 | c.3825G>A p.A1275= | Silent (SNP) | VAF 140/328 reads (43%) | catalogued as rs1197881163; called by muse, mutect2, varscan2
- RYR3 | c.2118T>C p.G706= | Silent (SNP) | VAF 58/217 reads (27%) | called by muse, mutect2, varscan2
- SCAF1 | c.1059C>T p.F353= | Silent (SNP) | VAF 134/435 reads (31%) | catalogued as rs777276344, COSV62182468; called by muse, mutect2, varscan2
- SCARF1 | c.1026C>T p.C342= | Silent (SNP) | VAF 91/281 reads (32%) | catalogued as rs768019068; called by muse, mutect2, varscan2
- SETD2 | c.3093G>A p.V1031= | Silent (SNP) | VAF 74/164 reads (45%) | called by muse, mutect2, varscan2
- SEZ6L2 | c.1917G>A p.P639= (on ENST00000308713 / NM_001114099.3; = p.P569= on NM_012410.4) | Silent (SNP) | VAF 15/352 reads (4%) | catalogued as rs1283159869; called by muse, mutect2
- SHPK | c.1314C>T p.D438= | Silent (SNP) | VAF 112/375 reads (30%) | catalogued as rs376637791; called by muse, mutect2, varscan2
- SLC25A52 | c.522G>A p.L174= (on ENST00000672005; = p.L164= on NM_001034172.4) | Silent (SNP) | VAF 113/327 reads (35%) | catalogued as COSV52501416; called by muse, mutect2, varscan2
- SLC44A2 | c.1068C>T p.Y356= | Silent (SNP) | VAF 86/264 reads (33%) | catalogued as rs762767390; called by muse, mutect2, varscan2
- SLC4A2 | c.3594G>A p.P1198= | Silent (SNP) | VAF 119/357 reads (33%) | catalogued as rs567874460; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC5A5 | c.165G>A p.A55= | Silent (SNP) | VAF 167/483 reads (35%) | catalogued as rs1358051585; called by muse, mutect2, varscan2
- SLU7 | c.1407T>C p.C469= | Silent (SNP) | VAF 74/225 reads (33%) | called by muse, mutect2
- SSC4D | c.738T>C p.Y246= | Silent (SNP) | VAF 166/524 reads (32%) | catalogued as rs1421314021; called by muse, mutect2, varscan2
- SYT3 | c.834T>C p.T278= | Silent (SNP) | VAF 151/443 reads (34%) | called by muse, mutect2, varscan2
- SYTL3 | c.192G>A p.A64= | Silent (SNP) | VAF 46/704 reads (7%) | catalogued as rs145322949; called by muse, mutect2
- TAF11L12 | c.27G>A p.A9= | Silent (SNP) | VAF 54/182 reads (30%) | catalogued as rs374660585; called by muse, mutect2, varscan2
- TBX18 | c.171C>T p.R57= | Silent (SNP) | VAF 177/720 reads (25%) | catalogued as rs774770434; called by muse, mutect2, varscan2
- TINF2 | c.660T>G p.P220= | Silent (SNP) | VAF 68/237 reads (29%) | called by muse, mutect2, varscan2
- TLCD3A | c.484C>T p.L162= | Silent (SNP) | VAF 71/256 reads (28%) | called by muse, mutect2, varscan2
- TLE3 | c.1554C>T p.G518= | Silent (SNP) | VAF 73/285 reads (26%) | called by muse, mutect2, varscan2
- TMEM132A | c.1080C>T p.G360= (on ENST00000453848 / NM_178031.3; = p.G361= on NM_017870.4) | Silent (SNP) | VAF 91/308 reads (30%) | catalogued as rs746985632; called by muse, mutect2, varscan2
- TMEM200B | c.483C>T p.D161= | Silent (SNP) | VAF 150/491 reads (31%) | called by muse, mutect2, varscan2
- TNRC6C | c.2070A>G p.T690= | Silent (SNP) | VAF 125/367 reads (34%) | called by muse, mutect2, varscan2
- TNXB | c.8352G>A p.S2784= (on ENST00000647633; = p.S2537= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 118/598 reads (20%) | catalogued as rs1476480355, COSV64486096; called by muse, mutect2, varscan2
- TOR4A | c.201G>A p.P67= | Silent (SNP) | VAF 185/573 reads (32%) | called by muse, mutect2, varscan2
- TRPA1 | c.57C>T p.G19= | Silent (SNP) | VAF 76/280 reads (27%) | called by muse, varscan2
- TRPV3 | c.93G>A p.P31= | Silent (SNP) | VAF 78/281 reads (28%) | catalogued as rs150128236; called by muse, mutect2, varscan2
- TSC2 | c.2493G>A p.T831= | Silent (SNP) | VAF 104/326 reads (32%) | catalogued as rs773645613, COSV54772276; called by muse, mutect2, varscan2
- TSNAXIP1 | c.723G>A p.T241= | Silent (SNP) | VAF 135/407 reads (33%) | catalogued as rs770461088, COSV54649371; called by muse, mutect2, varscan2
- TSPAN17 | c.978G>A p.E326= | Silent (SNP) | VAF 68/242 reads (28%) | called by muse, mutect2, varscan2
- TSPAN32 | c.921C>T p.R307= | Silent (SNP) | VAF 86/272 reads (32%) | catalogued as rs529106769, COSV51718498; called by muse, mutect2, varscan2
- TTC34 | c.2442C>T p.I814= | Silent (SNP) | VAF 160/480 reads (33%) | catalogued as rs950941829; called by muse, mutect2, varscan2
- UNC5B | c.1578C>T p.S526= | Silent (SNP) | VAF 127/440 reads (29%) | catalogued as rs775350591, COSV58979039; called by muse, mutect2, varscan2
- USP20 | c.2679G>A p.A893= | Silent (SNP) | VAF 107/370 reads (29%) | catalogued as rs770163008; called by muse, mutect2, varscan2
- VPS13D | c.2838C>T p.R946= | Silent (SNP) | VAF 100/282 reads (35%) | catalogued as rs755308689, COSV99165492; called by muse, mutect2, varscan2
- VWF | c.5673C>T p.D1891= | Silent (SNP) | VAF 62/205 reads (30%) | catalogued as rs369450995; called by muse, mutect2, varscan2
- WDR3 | c.1299T>C p.A433= | Silent (SNP) | VAF 65/161 reads (40%) | catalogued as rs1439903531; called by muse, mutect2, varscan2
- WDR62 | c.1695C>T p.N565= | Silent (SNP) | VAF 58/206 reads (28%) | catalogued as rs138387192, COSV54335480; ClinVar: likely benign; called by muse, mutect2, varscan2
- XRN2 | c.2352T>C p.S784= | Silent (SNP) | VAF 71/211 reads (34%) | called by muse, mutect2, varscan2
- ZAN | c.3552G>A p.Q1184= | Silent (SNP) | VAF 63/195 reads (32%) | called by muse, mutect2, varscan2
- ZBED4 | c.2214C>T p.N738= | Silent (SNP) | VAF 78/284 reads (27%) | called by muse, mutect2, varscan2
- ZFHX4 | c.654A>G p.A218= | Silent (SNP) | VAF 64/191 reads (34%) | catalogued as rs778416005; called by muse, mutect2, varscan2
- ZFHX4 | c.10695A>G p.Q3565= | Silent (SNP) | VAF 81/266 reads (30%) | called by muse, mutect2, varscan2
- ZNF256 | c.1515G>A p.T505= | Silent (SNP) | VAF 95/304 reads (31%) | catalogued as rs756411703; called by muse, mutect2, varscan2
- ZNF467 | c.1353C>T p.R451= | Silent (SNP) | VAF 29/746 reads (4%) | catalogued as COSV57372762; called by muse, mutect2
- ZNF496 | c.1537C>T p.L513= | Silent (SNP) | VAF 101/298 reads (34%) | called by muse, mutect2, varscan2
- ZNF563 | c.1287G>A p.A429= | Silent (SNP) | VAF 73/263 reads (28%) | catalogued as rs139708657; called by muse, mutect2, varscan2
- ZNF606 | c.609A>G p.Q203= | Silent (SNP) | VAF 14/344 reads (4%) | catalogued as rs1312777259; called by muse, mutect2
- ZNF624 | c.870G>A p.L290= | Silent (SNP) | VAF 62/217 reads (29%) | called by muse, mutect2, varscan2
- ZNF836 | c.702T>C p.I234= | Silent (SNP) | VAF 84/266 reads (32%) | called by muse, mutect2, varscan2
- AC010980.1 | chr2:222321455 ins T | 5'Flank (INS) | VAF 60/190 reads (32%) | catalogued as rs971028776; called by mutect2, varscan2
- AFAP1 | c.1531-2521G>A | Intron (SNP) | VAF 53/178 reads (30%) | catalogued as rs370852242; called by muse, mutect2, varscan2
- ALDH1A3 | c.99+23C>A | Intron (SNP) | VAF 209/608 reads (34%) | called by muse, mutect2, varscan2
- ATP6V0B | c.67+97del | Intron (DEL) | VAF 141/537 reads (26%) | called by mutect2, pindel, varscan2
- C4orf50 | c.-1057G>A | 5'UTR (SNP) | VAF 79/273 reads (29%) | catalogued as rs569284166; called by muse, mutect2, varscan2
- C8orf34 | c.1549+3294A>T | Intron (SNP) | VAF 48/151 reads (32%) | called by muse, mutect2, varscan2
- CASP10 | c.685-3268dup | Intron (INS) | VAF 64/198 reads (32%) | called by mutect2, varscan2
- DCHS2 | n.8536T>C | RNA (SNP) | VAF 72/317 reads (23%) | catalogued as COSV61778179; called by muse, mutect2, varscan2
- DCHS2 | n.1300G>A | RNA (SNP) | VAF 16/430 reads (4%) | called by muse, mutect2
- FN1 | c.3797-1337C>T | Intron (SNP) | VAF 75/233 reads (32%) | catalogued as rs552329557; called by muse, mutect2, varscan2
- FSIP2 | chr2:185738663 T>C | 5'Flank (SNP) | VAF 83/274 reads (30%) | called by muse, mutect2, varscan2
- HYDIN | c.-10del | 5'UTR (DEL) | VAF 54/134 reads (40%) | catalogued as rs768899959; called by mutect2, varscan2
- RAB11FIP5 | c.1569-5138del | Intron (DEL) | VAF 84/352 reads (24%) | called by mutect2, pindel, varscan2
- RIMBP2 | c.2362-1802G>A | Intron (SNP) | VAF 100/341 reads (29%) | catalogued as rs1165423654; called by muse, varscan2
- RNU6-1178P | chr17:20895974 G>A | 5'Flank (SNP) | VAF 91/316 reads (29%) | catalogued as rs748932387, COSV60002804; called by muse, mutect2, varscan2
7 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 7 other) are not listed here.
